Somatic mutation profile of tumor specimen TCGA-60-2714-01A (aliquot TCGA-60-2714-01A-01D-1522-08) from TCGA case TCGA-60-2714, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 66.2 years (24,169 days).
Specimen TCGA-60-2714-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 044c1062-8f10-4902-b6a5-d339a86909dd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-60-2714-11A (Solid Tissue Normal), aliquot TCGA-60-2714-11A-01D-1522-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e8863d1f-0b08-477f-8c8e-b56fa6dfb35f

The open-access MAF lists 919 somatic variants for this specimen: 714 protein-altering or splice-affecting, 183 silent, 22 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 627, Silent 183, Nonsense Mutation 44, Splice Site 17, Frame Shift Del 13, RNA 13, Frame Shift Ins 7, Splice Region 6, Intron 5, 3'UTR 2, 3'Flank 1, 5'Flank 1.

Variants (750 of 919; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL6A3 | c.1393C>T p.R465* | Nonsense Mutation (SNP) | VAF 18/106 reads (17%) | catalogued as rs121434554, CM021076, COSV55086452; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.392A>T p.N131I | Missense Mutation (SNP) | VAF 25/43 reads (58%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1131691037, CM087281, CM159290, COSV52670715, COSV52718021, COSV53252418; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ABCA3 | c.1467+1G>T p.X489_splice | Splice Site (SNP) | VAF 14/66 reads (21%) | catalogued as COSV100069138; called by muse, varscan2
- ABCA3 | c.1467G>T p.M489I | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV100069140; called by muse, mutect2, varscan2
- ABCA6 | c.4165G>A p.A1389T | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.2); catalogued as COSV99447741; called by muse, varscan2
- ABCA6 | c.4114A>T p.R1372W | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs142075639; called by muse, varscan2
- ABCC12 | c.1846G>A p.A616T | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs569747930, COSV60918157; called by muse, mutect2, varscan2
- ABCC4 | c.2218A>T p.N740Y | Missense Mutation (SNP) | VAF 70/271 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as COSV100972802; called by muse, mutect2, varscan2
- ABHD16B | c.507C>A p.H169Q | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.46); PolyPhen benign (0.013); catalogued as COSV99410786, COSV99410890; called by muse, mutect2, varscan2
- ABHD17A | c.191G>A p.G64E | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as COSV99171386; called by muse, mutect2, varscan2
- ABRA | c.967C>A p.H323N | Missense Mutation (SNP) | VAF 103/212 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.086); catalogued as COSV100357660; called by muse, mutect2, varscan2
- AC011448.1 | c.24G>T p.Q8H | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99389289; called by muse, mutect2, varscan2
- ACP3 | c.678G>T p.W226C | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100313591; called by muse, mutect2, varscan2
- ACSM2A | c.1212del p.G405Afs*16 (on ENST00000219054; = p.G326Afs*16 on NM_001308169.2) | Frame Shift Del (DEL) | VAF 87/240 reads (36%) | catalogued as rs755296455; called by mutect2, pindel, varscan2
- ACSS3 | c.1477A>T p.K493* | Nonsense Mutation (SNP) | VAF 20/166 reads (12%) | catalogued as COSV99699477; called by muse, mutect2, varscan2
- ACTG2 | c.865G>T p.D289Y | Missense Mutation (SNP) | VAF 33/59 reads (56%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as COSV100609515; called by muse, mutect2, varscan2
- ADAMTS1 | c.2186G>T p.G729V | Missense Mutation (SNP) | VAF 65/150 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99536542; called by muse, mutect2, varscan2
- ADCY2 | c.1120G>C p.D374H | Missense Mutation (SNP) | VAF 130/315 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100604170; called by muse, mutect2, varscan2
- ADCY5 | c.2538C>A p.F846L | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as COSV100568271, COSV59199932; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.1376C>A p.S459Y | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100416959, COSV58445671; called by muse, mutect2, varscan2
- ADGRB1 | c.1754A>T p.N585I | Missense Mutation (SNP) | VAF 45/257 reads (18%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.773); catalogued as COSV100030396; called by muse, mutect2, varscan2
- ADGRB3 | c.2951T>C p.L984S | Missense Mutation (SNP) | VAF 129/221 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99486902; called by muse, mutect2, varscan2
- ADGRL2 | c.2981T>C p.F994S (on ENST00000370717 / NM_001366005.1; = p.F981S on NM_012302.4) | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99591636; called by muse, mutect2
- ADGRV1 | c.9472G>C p.D3158H | Missense Mutation (SNP) | VAF 63/202 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV67995946; called by muse, mutect2, varscan2
- ADIPOR1 | c.264G>T p.W88C | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100579674; called by muse, mutect2, varscan2
- AFF3 | c.1092-2A>T p.X364_splice | Splice Site (SNP) | VAF 40/258 reads (16%) | catalogued as COSV100420126; called by muse, mutect2, varscan2
- AGAP3 | c.1241G>A p.G414D (on ENST00000622464; = p.G450D on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/167 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101257440; called by muse, mutect2, varscan2
- AGBL4 | c.1229G>C p.S410T | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV100484621; called by muse, mutect2, varscan2
- AGMO | c.1308G>A p.M436I | Missense Mutation (SNP) | VAF 32/230 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100694613, COSV100694753; called by muse, mutect2, varscan2
- AGPAT4 | c.178+2T>A p.X60_splice | Splice Site (SNP) | VAF 10/37 reads (27%) | catalogued as COSV100212109; called by muse, mutect2, varscan2
- AHNAK2 | c.14917C>T p.P4973S | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.033); catalogued as COSV100318995; called by muse, mutect2, varscan2
- AHNAK2 | c.10327G>T p.V3443F | Missense Mutation (SNP) | VAF 37/293 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as COSV100318996, COSV60917774; called by muse, mutect2, varscan2
- AHNAK2 | c.1381G>A p.G461R | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.549); catalogued as rs754074625, COSV100318997, COSV100319122; called by muse, mutect2, varscan2
- AK5 | c.832T>A p.F278I (on ENST00000354567 / NM_174858.3; = p.F252I on NM_012093.4) | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100643399; called by muse, mutect2, varscan2
- ALDOB | c.58G>T p.A20S | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs575202673, COSV100878926; called by muse, mutect2, varscan2
- ALPK3 | c.2077C>T p.Q693* | Nonsense Mutation (SNP) | VAF 21/70 reads (30%) | catalogued as COSV99362024; called by muse, mutect2, varscan2
- AMER3 | c.1555C>A p.R519S | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.587); catalogued as COSV100366265; called by muse, varscan2
- ANAPC2 | c.1153C>T p.R385W | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100119245; called by muse, mutect2, varscan2
- ANKRD17 | c.3212C>T p.P1071L | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV100430006; called by muse, mutect2, varscan2
- ANO5 | c.1817G>A p.C606Y | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100202237; called by muse, mutect2, varscan2
- APAF1 | c.1481C>T p.A494V (on ENST00000551964 / NM_181861.2; = p.A483V on NM_001160.3) | Missense Mutation (SNP) | VAF 73/186 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs143963802; called by muse, mutect2, varscan2
- APCS | c.418C>A p.Q140K | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99661521; called by muse, mutect2, varscan2
- APOB | c.12325C>A p.Q4109K | Missense Mutation (SNP) | VAF 182/324 reads (56%) | SIFT tolerated (0.1); PolyPhen benign (0.067); catalogued as rs928519754, COSV99268179; called by muse, mutect2, varscan2
- AQP3 | c.797G>C p.G266A | Missense Mutation (SNP) | VAF 37/198 reads (19%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.998); catalogued as COSV99955703; called by muse, varscan2
- ARHGAP30 | c.2977G>A p.G993S (on ENST00000368013 / NM_001025598.2; = p.G782S on NM_181720.3) | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746429914, COSV100920510; called by muse, mutect2, varscan2
- ARHGAP5 | c.225G>T p.W75C | Missense Mutation (SNP) | VAF 42/355 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100565709; called by muse, mutect2, varscan2
- ARHGEF17 | c.2812G>A p.E938K | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.007); catalogued as rs147085966; called by muse, varscan2
- ARID3B | c.491C>A p.A164D | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as COSV100654759; called by muse, mutect2, varscan2
- ASB17 | c.857G>A p.R286H | Missense Mutation (SNP) | VAF 34/160 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.392); catalogued as rs149522654; called by muse, mutect2, varscan2
- ASTN2 | c.1081G>A p.A361T | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs753224709, COSV100529938; called by muse, mutect2, varscan2
- ASXL3 | c.2540C>A p.P847H | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.338); catalogued as COSV99326654; called by muse, mutect2, varscan2
- ATAD5 | c.1609G>A p.E537K | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV100430231; called by muse, mutect2, varscan2
- ATP2B2 | c.1164G>T p.K388N (on ENST00000352432; = p.K354N on NM_001683.5) | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV100660502; called by muse, mutect2, varscan2
- ATP9A | c.562C>T p.R188W | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58765058; called by muse, mutect2, varscan2
- AZGP1 | c.778G>A p.G260S | Missense Mutation (SNP) | VAF 37/146 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.758); catalogued as COSV99448223, COSV99448237; called by muse, mutect2, varscan2
- B4GALNT2 | c.1004A>G p.K335R | Missense Mutation (SNP) | VAF 93/251 reads (37%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.526); catalogued as rs1253018157, COSV100302773; called by muse, mutect2, varscan2
- BAAT | c.842C>G p.S281C | Missense Mutation (SNP) | VAF 23/146 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.166); catalogued as COSV52289965, COSV99408683; called by muse, mutect2, varscan2
- BARD1 | c.2111G>T p.S704I | Missense Mutation (SNP) | VAF 55/104 reads (53%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs764477334, COSV99639890; ClinVar: likely benign; called by muse, mutect2, varscan2
- BCAN | c.1294C>A p.L432I | Missense Mutation (SNP) | VAF 69/151 reads (46%) | SIFT tolerated (0.27); PolyPhen benign (0.164); catalogued as COSV61259816; called by muse, mutect2, varscan2
- BCO1 | c.590T>A p.V197E | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.776); catalogued as COSV99258688; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.3466A>T p.R1156W | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV100863953; called by muse, mutect2
- BMPER | c.1796G>T p.C599F | Missense Mutation (SNP) | VAF 44/390 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51821104, COSV99780589; called by muse, mutect2, varscan2
- BNC2 | c.1172C>A p.T391N | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV101034489; called by muse, mutect2, varscan2
- BRCA1 | c.3404A>T p.Q1135L | Missense Mutation (SNP) | VAF 29/242 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.465); catalogued as COSV100525129; called by muse, mutect2, varscan2
- BRD8 | c.506-2A>T p.X169_splice | Splice Site (SNP) | VAF 45/134 reads (34%) | catalogued as COSV99137673; called by muse, mutect2, varscan2
- BRWD3 | c.4362C>A p.S1454R | Missense Mutation (SNP) | VAF 287/587 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.655); catalogued as COSV100956561; called by muse, varscan2
- BRWD3 | c.1664T>G p.M555R | Missense Mutation (SNP) | VAF 15/190 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV100956562; called by muse, mutect2
- BSND | c.548+1G>A p.X183_splice | Splice Site (SNP) | VAF 44/86 reads (51%) | catalogued as rs765766484, COSV100987661; called by muse, mutect2, varscan2
- BTAF1 | c.1309G>C p.E437Q | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV99795847; called by muse, mutect2
- BTN1A1 | c.1436C>A p.P479H | Missense Mutation (SNP) | VAF 106/188 reads (56%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.838); catalogued as COSV99764564; called by muse, mutect2, varscan2
- BUB1 | c.3075G>T p.L1025F | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.836); catalogued as COSV100241672; called by muse, mutect2, varscan2
- BUD31 | c.412G>T p.G138C | Missense Mutation (SNP) | VAF 76/180 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99464575; called by muse, mutect2, varscan2
- C11orf1 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99500330; called by muse, mutect2
- C15orf39 | c.1679G>T p.G560V | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.159); catalogued as COSV100641478; called by muse, mutect2, varscan2
- C22orf31 | c.167C>G p.P56R | Missense Mutation (SNP) | VAF 36/186 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.509); catalogued as COSV99326522; called by muse, mutect2, varscan2
- C2CD2 | c.1634A>T p.E545V | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.36); catalogued as COSV100298426; called by muse, mutect2
- C2orf16 | c.2497G>A p.E833K | Missense Mutation (SNP) | VAF 51/252 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.66); catalogued as COSV100821033; called by muse, mutect2, varscan2
- C3AR1 | c.731G>T p.R244M | Missense Mutation (SNP) | VAF 20/194 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV99368993; called by muse, mutect2, varscan2
- C6 | c.411G>T p.E137D | Missense Mutation (SNP) | VAF 113/284 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as rs142045537; called by muse, mutect2, varscan2
- C7orf50 | c.129G>A p.K43= | Splice Region (SNP) | VAF 38/76 reads (50%) | catalogued as rs770215840, COSV100657446, COSV100657720; called by muse, mutect2, varscan2
- C9 | c.153G>A p.W51* | Nonsense Mutation (SNP) | VAF 45/192 reads (23%) | catalogued as COSV99662567; called by muse, mutect2, varscan2
- C9orf131 | c.2966C>A p.P989H | Missense Mutation (SNP) | VAF 84/184 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.443); catalogued as COSV100398322; called by muse, varscan2
- CA4 | c.656G>A p.R219H | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769858478, COSV99958187; called by muse, mutect2, varscan2
- CACNA1C | c.3717G>T p.Q1239H | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100222350; called by muse, mutect2, varscan2
- CACNA1E | c.5149C>G p.L1717V | Missense Mutation (SNP) | VAF 69/439 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100705409; called by muse, mutect2, varscan2
- CAMSAP2 | c.83C>G p.S28C | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV99374358; called by muse, mutect2
- CARD17 | c.291T>A p.N97K | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV100995287; called by muse, mutect2
- CASD1 | c.211A>T p.M71L | Missense Mutation (SNP) | VAF 16/245 reads (7%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV99803093; called by muse, mutect2
- CASKIN1 | c.538C>T p.R180W | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1192919208, COSV58871919; called by muse, mutect2, varscan2
- CC2D1A | c.605C>T p.A202V | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs375001092; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC157 | c.458C>A p.P153H | Missense Mutation (SNP) | VAF 138/357 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100199848; called by muse, mutect2, varscan2
- CCSER2 | c.1913A>T p.Y638F | Missense Mutation (SNP) | VAF 55/214 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as rs753359820, COSV99826537; called by muse, mutect2, varscan2
- CD200R1 | c.188C>A p.P63H (on ENST00000471858 / NM_170780.3; = p.P86H on NM_138806.4) | Missense Mutation (SNP) | VAF 72/166 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.062); catalogued as COSV55600921, COSV99867842; called by muse, mutect2, varscan2
- CD300LD | c.65C>A p.T22N | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.518); catalogued as COSV100032663; called by muse, mutect2, varscan2
- CDC20B | c.712G>C p.D238H | Missense Mutation (SNP) | VAF 72/147 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99697426; called by muse, mutect2, varscan2
- CDH10 | c.1975G>T p.D659Y | Missense Mutation (SNP) | VAF 105/251 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100050393, COSV52570059; called by muse, mutect2, varscan2
- CDH10 | c.1624G>C p.D542H | Missense Mutation (SNP) | VAF 70/330 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100053159; called by muse, mutect2, varscan2
- CDH18 | c.2127C>A p.S709R | Missense Mutation (SNP) | VAF 60/158 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.139); catalogued as COSV99935584; called by muse, mutect2, varscan2
- CDHR1 | c.334G>T p.D112Y | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100259394; called by muse, mutect2, varscan2
- CELSR1 | c.8632G>A p.G2878S | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT tolerated (0.53); PolyPhen benign (0.083); catalogued as rs912620757, CM143051, COSV99420076; called by muse, mutect2, varscan2
- CELSR2 | c.6179G>T p.R2060L | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as COSV99603466; called by muse, mutect2, varscan2
- CELSR3 | c.1322C>A p.T441N | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.145); catalogued as COSV99375045; called by muse, mutect2
- CEMIP | c.1879C>A p.H627N | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99587310; called by muse, mutect2, varscan2
- CFAP58 | c.217G>T p.V73L | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.009); catalogued as COSV100459129; called by muse, mutect2, varscan2
- CFAP61 | c.2911G>T p.D971Y | Missense Mutation (SNP) | VAF 71/267 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99846687; called by muse, mutect2, varscan2
- CFAP91 | c.1313G>T p.R438M | Missense Mutation (SNP) | VAF 68/181 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV99847513; called by muse, mutect2, varscan2
- CFAP94 | c.1576A>G p.I526V (on ENST00000320267 / NM_001352064.2; = p.I532V on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as COSV100209758; called by muse, mutect2, varscan2
- CFH | c.254G>T p.C85F | Missense Mutation (SNP) | VAF 61/240 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100661454, COSV100661655; called by muse, mutect2, varscan2
- CFHR2 | c.429T>A p.T143= | Splice Region (SNP) | VAF 23/145 reads (16%) | catalogued as rs1217237935, COSV66382043; called by muse, mutect2, varscan2
- CGB5 | c.339C>A p.C113* | Nonsense Mutation (SNP) | VAF 15/120 reads (13%) | catalogued as COSV100032133; called by muse, varscan2
- CHD5 | c.2639A>G p.Q880R | Missense Mutation (SNP) | VAF 42/167 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as COSV99315094; called by muse, mutect2, varscan2
- CHMP4C | c.353C>T p.S118F | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as COSV51928834; called by muse, mutect2, varscan2
- CHST1 | c.599G>C p.R200P | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.406); catalogued as COSV100346544, COSV57326190; called by muse, mutect2, varscan2
- CLBA1 | c.11G>T p.R4L | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.127); catalogued as rs890875027, COSV101121123; called by muse, mutect2, varscan2
- CLCN4 | c.688G>T p.V230L | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.131); catalogued as COSV101074075; called by muse, mutect2, varscan2
- CLN5 | c.449G>T p.R150L | Missense Mutation (SNP) | VAF 101/309 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.156); catalogued as rs1014000261, COSV66283955; called by muse, mutect2, varscan2
- CLVS1 | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.27); catalogued as COSV100369836, COSV100370711; called by muse, mutect2, varscan2
- CNGB3 | c.367G>C p.V123L | Missense Mutation (SNP) | VAF 225/739 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs1403535781, COSV100183095; called by muse, mutect2, varscan2
- CNKSR2 | c.1268G>T p.S423I | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV99669816; called by muse, mutect2, varscan2
- CNKSR2 | c.2504T>A p.L835Q | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV99669818; called by muse, mutect2, varscan2
- CNTLN | c.1405G>T p.E469* | Nonsense Mutation (SNP) | VAF 57/276 reads (21%) | catalogued as COSV99265738; called by muse, mutect2, varscan2
- CNTNAP2 | c.2262G>T p.K754N | Missense Mutation (SNP) | VAF 41/211 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100665030, COSV62257249; called by muse, mutect2, varscan2
- CNTNAP2 | c.2785G>T p.G929C | Missense Mutation (SNP) | VAF 24/159 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV100665060, COSV100673046; called by muse, mutect2, varscan2
- COG7 | c.1663G>A p.E555K | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); catalogued as COSV100207828; called by muse, mutect2
- COL14A1 | c.2977G>T p.E993* | Nonsense Mutation (SNP) | VAF 91/178 reads (51%) | catalogued as COSV99920720; called by muse, mutect2, varscan2
- COL20A1 | c.3529G>T p.G1177* | Nonsense Mutation (SNP) | VAF 5/12 reads (42%) | catalogued as COSV100491461; called by muse, mutect2, varscan2
- COL28A1 | c.783C>G p.I261M | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.529); catalogued as rs761066719, COSV101258950; called by muse, mutect2
- COL3A1 | c.2730C>A p.N910K | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV100483748; called by muse, mutect2, varscan2
- COL6A3 | c.4064C>A p.P1355Q | Missense Mutation (SNP) | VAF 35/56 reads (63%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.65); catalogued as COSV99801569; called by muse, mutect2, varscan2
- COL6A5 | c.6166G>A p.A2056T (on ENST00000312481; = p.A2052T on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as COSV55215922; called by muse, mutect2, varscan2
- CPD | c.2224G>A p.V742M | Missense Mutation (SNP) | VAF 20/254 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56711787; called by muse, mutect2
- CPE | c.1213+1G>T p.X405_splice | Splice Site (SNP) | VAF 6/68 reads (9%) | catalogued as COSV101291734; called by muse, mutect2
- CPNE6 | c.1156G>A p.E386K | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.824); catalogued as COSV99393788; called by muse, mutect2, varscan2
- CPVL | c.1424T>A p.V475D | Missense Mutation (SNP) | VAF 31/149 reads (21%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0); catalogued as COSV99606443; called by muse, varscan2
- CRX | c.749C>G p.P250R | Missense Mutation (SNP) | VAF 102/212 reads (48%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.977); catalogued as COSV99704658; called by muse, mutect2, varscan2
- CRYBA4 | c.568A>T p.S190C | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100697865; called by muse, mutect2, varscan2
- CRYBB1 | c.95C>T p.S32F | Missense Mutation (SNP) | VAF 32/139 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.205); catalogued as COSV99316221; called by muse, mutect2, varscan2
- CSF2RB | c.2398C>A p.P800T | Missense Mutation (SNP) | VAF 65/171 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV99454477; called by muse, mutect2, varscan2
- CSMD1 | c.4108G>C p.D1370H (on ENST00000520002; = p.D1369H on NM_033225.6) | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV100153843; called by muse, varscan2
- CSMD2 | c.8389C>T p.R2797W | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.927); catalogued as rs746116665, COSV53890915; called by muse, mutect2, varscan2
- CSMD2 | c.1494C>A p.F498L | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.89); PolyPhen benign (0.023); catalogued as COSV99595518; called by muse, mutect2, varscan2
- CSMD3 | c.9002C>A p.P3001H (on ENST00000297405 / NM_001363185.1; = p.P2832H on NM_052900.3) | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99829319, COSV99848060; called by muse, mutect2
- CSMD3 | c.7937C>A p.T2646K (on ENST00000297405 / NM_001363185.1; = p.T2542K on NM_052900.3) | Missense Mutation (SNP) | VAF 52/201 reads (26%) | SIFT tolerated (0.94); PolyPhen possibly damaging (0.506); catalogued as COSV99848065; called by muse, mutect2, varscan2
- CSMD3 | c.1509-1G>T p.X503_splice (on ENST00000297405 / NM_001363185.1; = p.X399_splice on NM_052900.3) | Splice Site (SNP) | VAF 44/217 reads (20%) | catalogued as COSV99848066; called by muse, mutect2, varscan2
- CSN1S1 | c.305A>T p.Q102L | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.188); catalogued as rs1405199605, COSV99886951; called by muse, mutect2, varscan2
- CTNNA3 | c.354G>T p.R118S | Missense Mutation (SNP) | VAF 48/146 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100373890; called by muse, mutect2, varscan2
- CTNNA3 | c.353G>T p.R118M | Missense Mutation (SNP) | VAF 45/142 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100373894; called by muse, varscan2
- CTNND2 | c.1310T>A p.L437H | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.707); catalogued as COSV100481157; called by muse, mutect2, varscan2
- CUBN | c.7606A>G p.I2536V | Missense Mutation (SNP) | VAF 8/135 reads (6%) | SIFT tolerated (0.98); PolyPhen benign (0.019); catalogued as COSV100913565; called by muse, mutect2
- CUL3 | c.1843-1G>T p.X615_splice | Splice Site (SNP) | VAF 52/157 reads (33%) | catalogued as COSV100024780; called by muse, mutect2, varscan2
- CUTC | c.192G>T p.M64I | Missense Mutation (SNP) | VAF 93/285 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV100976188; called by muse, mutect2, varscan2
- CUX2 | c.3670C>A p.R1224S | Missense Mutation (SNP) | VAF 77/218 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV55627829, COSV99920801; called by muse, mutect2, varscan2
- CYB561 | c.463C>G p.R155G | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.017); catalogued as COSV100669192; called by muse, mutect2, varscan2
- CYP21A2 | c.137C>A p.P46H | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as CM128448, COSV100926662; called by muse, mutect2, varscan2
- CYP2R1 | c.322G>T p.D108Y | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100585006; called by muse, mutect2, varscan2
- CYP8B1 | c.499G>T p.D167Y | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100296301; called by muse, mutect2, varscan2
- DBI | c.128-2A>C p.X43_splice (on ENST00000355857 / NM_001079862.3; = p.X60_splice on NM_020548.8 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 8/82 reads (10%) | catalogued as COSV100276055; called by muse, mutect2, varscan2
- DCAF17 | c.1205C>T p.T402I | Missense Mutation (SNP) | VAF 48/104 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764124723, COSV100266393; called by muse, mutect2, varscan2
- DCAF8L1 | c.179T>G p.L60R | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as COSV101491548; called by muse, mutect2, varscan2
- DCC | c.2920A>C p.N974H | Missense Mutation (SNP) | VAF 56/159 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100503167; called by muse, mutect2, varscan2
- DDC | c.856C>A p.H286N | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.843); catalogued as COSV100779756; called by muse, mutect2, varscan2
- DDX23 | c.296G>C p.R99P | Missense Mutation (SNP) | VAF 61/546 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.453); catalogued as COSV100339970, COSV57284993; called by muse, mutect2, varscan2
- DDX58 | c.2450C>T p.A817V | Missense Mutation (SNP) | VAF 11/278 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as COSV100008669; called by muse, mutect2
- DDX59 | c.1057G>T p.D353Y | Missense Mutation (SNP) | VAF 37/318 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100494709; called by muse, mutect2, varscan2
- DENND2A | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 33/290 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.586); catalogued as rs868619288, COSV52058672; called by muse, mutect2, varscan2
- DIAPH2 | c.2771T>C p.V924A | Missense Mutation (SNP) | VAF 48/137 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV100235403; called by muse, mutect2, varscan2
- DISC1 | c.799A>T p.S267C | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.719); catalogued as COSV99697319, COSV99698653; called by muse, mutect2, varscan2
- DMBT1 | c.3415T>C p.Y1139H (on ENST00000338354 / NM_001377530.1; = p.Y640H on NM_004406.3) | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0.006); catalogued as COSV100354127; called by mutect2, varscan2
- DNAH11 | c.856G>T p.E286* | Nonsense Mutation (SNP) | VAF 8/40 reads (20%) | catalogued as COSV100176684; called by muse, mutect2, varscan2
- DNAH17 | c.11358C>G p.F3786L | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.681); catalogued as COSV101103504; called by muse, mutect2, varscan2
- DNAH17 | c.8044C>A p.R2682S | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV101103505; called by muse, mutect2, varscan2
- DNAH17 | c.3436C>G p.L1146V | Missense Mutation (SNP) | VAF 36/172 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs372653772, COSV101103506; called by muse, mutect2, varscan2
- DNAH7 | c.7308G>T p.K2436N | Missense Mutation (SNP) | VAF 55/105 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV100417626; called by muse, mutect2, varscan2
- DNAJC5B | c.163C>A p.P55T | Missense Mutation (SNP) | VAF 143/421 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); catalogued as COSV52538334, COSV99395949; called by muse, mutect2, varscan2
- DOCK2 | c.4583C>A p.S1528Y | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99915544; called by muse, mutect2, varscan2
- DPP4 | c.1379C>T p.S460L | Missense Mutation (SNP) | VAF 113/202 reads (56%) | SIFT tolerated (0.62); PolyPhen benign (0.105); catalogued as COSV100859106; called by muse, mutect2, varscan2
- DPYS | c.271C>T p.L91F | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as rs910567054, COSV100680140, COSV99080288; called by muse, mutect2, varscan2
- DSG2 | c.2229A>C p.E743D | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.011); catalogued as COSV99853565; called by muse, mutect2, varscan2
- DUSP6 | c.665C>A p.S222Y | Missense Mutation (SNP) | VAF 119/251 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54377940, COSV99684153; called by muse, mutect2, varscan2
- EDIL3 | c.152C>G p.P51R | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99679190; called by muse, mutect2, varscan2
- EFL1 | c.2393A>T p.E798V | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.118); catalogued as COSV51607522; called by muse, mutect2, varscan2
- EFR3A | c.1723G>T p.A575S | Missense Mutation (SNP) | VAF 70/404 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.049); catalogued as rs776395415, COSV99603628; called by muse, mutect2, varscan2
- EHHADH | c.843G>T p.W281C | Missense Mutation (SNP) | VAF 72/198 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99213368; called by muse, mutect2, varscan2
- ELK3 | c.839C>G p.S280C | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.436); catalogued as COSV99957804; called by muse, varscan2
- ELOA2 | c.377C>G p.P126R | Missense Mutation (SNP) | VAF 34/184 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.895); catalogued as COSV99798170; called by muse, mutect2, varscan2
- EMSY | c.1749G>T p.K583N | Missense Mutation (SNP) | VAF 30/215 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100596083; called by muse, mutect2, varscan2
- ENAM | c.2407C>A p.Q803K | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as COSV101253346; called by muse, mutect2, varscan2
- ENTHD1 | c.1276G>T p.D426Y | Missense Mutation (SNP) | VAF 50/110 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100289145; called by muse, mutect2, varscan2
- EOMES | c.1513C>G p.P505A | Missense Mutation (SNP) | VAF 83/230 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV99842318; called by muse, mutect2, varscan2
- EP300 | c.995C>T p.P332L | Missense Mutation (SNP) | VAF 116/266 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs754108081, COSV99609891; called by muse, mutect2, varscan2
- EP400 | c.3409G>A p.G1137S | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100202319; called by muse, mutect2
- EP400 | c.3410G>T p.G1137V | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100202322; called by muse, mutect2, varscan2
- EPB42 | c.1084T>C p.S362P (on ENST00000441366 / NM_001114134.2; = p.S392P on NM_000119.3) | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100282160; called by muse, mutect2
- EPC2 | c.535G>A p.V179M | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.652); catalogued as COSV99310220; called by muse, mutect2, varscan2
- EPHA3 | c.2518G>T p.G840C | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100348883, COSV60701975; called by muse, mutect2
- EPHA6 | c.1692T>A p.N564K | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV101065589; called by muse, mutect2, varscan2
- EPHA8 | c.2353C>A p.L785M | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99385751; called by muse, mutect2, varscan2
- EPS15L1 | c.1632G>C p.R544S | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.786); catalogued as COSV99933726; called by muse, mutect2, varscan2
- ERICH3 | c.1589del p.P530Lfs*9 | Frame Shift Del (DEL) | VAF 69/314 reads (22%) | catalogued as COSV58622639; called by mutect2, pindel, varscan2
- ESRP1 | c.1294G>T p.V432L | Missense Mutation (SNP) | VAF 17/227 reads (7%) | SIFT tolerated (0.78); PolyPhen benign (0.028); catalogued as COSV100619664; called by muse, mutect2
- ESRP1 | c.1543G>C p.D515H | Missense Mutation (SNP) | VAF 105/176 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV100619667, COSV64409200; called by muse, mutect2, varscan2
- ETFA | c.186+1G>T p.X62_splice | Splice Site (SNP) | VAF 35/148 reads (24%) | catalogued as COSV99144275; called by muse, mutect2, varscan2
- ETV3L | c.868G>T p.A290S | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.142); catalogued as rs935989348, COSV101485618; called by muse, mutect2, varscan2
- ETV3L | c.867G>T p.L289F | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.567); catalogued as rs771783360, COSV101485619; called by muse, mutect2, varscan2
- EXOC4 | c.1654A>C p.T552P | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as COSV99555817; called by muse, mutect2, varscan2
- EXTL3 | c.493G>C p.D165H | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.364); catalogued as rs375243395, COSV99594352; called by muse, mutect2, varscan2
- EZH2 | c.2053C>G p.R685G (on ENST00000460911 / NM_001203247.2; = p.R690G on NM_004456.5) | Missense Mutation (SNP) | VAF 64/393 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100236106, COSV100236878, COSV57445951; called by muse, mutect2, varscan2
- FAM135B | c.3565A>G p.T1189A | Missense Mutation (SNP) | VAF 28/233 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.526); catalogued as COSV99427797; called by muse, mutect2, varscan2
- FAM170A | c.292C>G p.R98G | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.04); catalogued as COSV100089350, COSV58925855; called by muse, mutect2, varscan2
- FAM214B | c.628A>T p.S210C | Missense Mutation (SNP) | VAF 43/85 reads (51%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.466); catalogued as COSV100521447; called by mutect2, varscan2
- FAM47A | c.2185G>T p.V729F | Missense Mutation (SNP) | VAF 58/205 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV100650092, COSV60494022; called by muse, mutect2, varscan2
- FAM76B | c.971C>G p.S324* | Nonsense Mutation (SNP) | VAF 26/201 reads (13%) | catalogued as COSV100716571; called by muse, mutect2, varscan2
- FANCI | c.3460C>T p.P1154S (on ENST00000310775 / NM_001376911.1; = p.P1094S on NM_018193.3) | Missense Mutation (SNP) | VAF 41/147 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100168582; called by muse, mutect2, varscan2
- FAP | c.1769G>A p.R590Q | Missense Mutation (SNP) | VAF 20/197 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as rs747747073, COSV51861339; called by muse, mutect2, varscan2
- FAT1 | c.5638G>A p.A1880T | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV101499651; called by muse, mutect2, varscan2
- FAT3 | c.10217G>T p.R3406L | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53103909; called by muse, mutect2, varscan2
- FAT3 | c.12594del p.A4199Pfs*65 | Frame Shift Del (DEL) | VAF 29/87 reads (33%) | catalogued as COSV99970537; called by mutect2, pindel, varscan2
- FAT4 | c.4228G>T p.V1410L | Missense Mutation (SNP) | VAF 61/257 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.98); catalogued as rs781736766, COSV101272852, COSV67881199, COSV67899529; called by muse, mutect2, varscan2
- FAT4 | c.9633T>A p.S3211R | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100630252; called by muse, mutect2, varscan2
- FBF1 | c.779G>T p.G260V (on ENST00000586717; = p.G274V on NM_001319193.1) | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100045604; called by muse, mutect2, varscan2
- FBXO8 | c.200G>T p.G67V | Missense Mutation (SNP) | VAF 24/168 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.333); catalogued as COSV101183747; called by muse, mutect2, varscan2
- FCGR1A | c.149G>T p.G50V | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.865); catalogued as COSV100977316; called by muse, mutect2, varscan2
- FCN1 | c.729T>A p.S243R | Missense Mutation (SNP) | VAF 24/248 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as COSV100878973; called by muse, mutect2
- FCN2 | c.231dup p.G78Wfs*57 | Frame Shift Ins (INS) | VAF 23/99 reads (23%) | catalogued as COSV99391224; called by mutect2, pindel, varscan2
- FEM1B | c.1495G>T p.D499Y | Missense Mutation (SNP) | VAF 57/248 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100183766, COSV60988396; called by muse, mutect2, varscan2
- FER1L6 | c.3380C>T p.S1127F | Missense Mutation (SNP) | VAF 244/450 reads (54%) | SIFT tolerated (0.15); PolyPhen benign (0.021); catalogued as COSV101206206; called by muse, varscan2
- FEZF2 | c.941T>G p.F314C | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99335009; called by muse, mutect2, varscan2
- FHL5 | c.715T>C p.C239R | Missense Mutation (SNP) | VAF 59/99 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as COSV100459812; called by muse, mutect2, varscan2
- FKBPL | c.46C>G p.Q16E | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.001); catalogued as COSV100913612; called by muse, mutect2
- FLG | c.2863C>T p.H955Y | Missense Mutation (SNP) | VAF 54/554 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.911); catalogued as COSV100912232; called by muse, mutect2
- FMO3 | c.1434G>T p.Q478H | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.489); catalogued as COSV100882557; called by muse, mutect2, varscan2
- FOXI1 | c.1011G>T p.W337C | Missense Mutation (SNP) | VAF 46/104 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as COSV100089619; called by muse, mutect2, varscan2
- FOXN3 | c.587G>C p.R196T | Missense Mutation (SNP) | VAF 27/184 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54307740, COSV99727504; called by muse, mutect2, varscan2
- FRMPD2 | c.1426C>A p.Q476K | Missense Mutation (SNP) | VAF 100/344 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV100564208; called by muse, mutect2, varscan2
- FSD2 | c.75C>A p.D25E | Missense Mutation (SNP) | VAF 45/160 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV100575294; called by muse, mutect2, varscan2
- FSHR | c.862C>A p.L288I | Missense Mutation (SNP) | VAF 97/197 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV100438116; called by muse, mutect2, varscan2
- FUT5 | c.322G>T p.A108S | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.539); catalogued as COSV99399002; called by muse, mutect2, varscan2
- G6PC | c.34G>T p.G12W | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99520979; called by muse, mutect2
- GAD1 | c.1697T>A p.F566Y | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100828020; called by muse, mutect2, varscan2
- GAD2 | c.975A>C p.K325N | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV52169940, COSV99394070; called by muse, mutect2, varscan2
- GALC | c.1850A>T p.Y617F | Missense Mutation (SNP) | VAF 39/329 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV99730592; called by muse, mutect2, varscan2
- GALC | c.399G>T p.L133F | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV99730598; called by muse, mutect2
- GANC | c.879G>T p.E293D | Missense Mutation (SNP) | VAF 9/43 reads (21%) | PolyPhen benign (0.001); catalogued as COSV100530570, COSV100531271; called by muse, mutect2, varscan2
- GATA2 | c.794T>A p.F265Y | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.752); catalogued as COSV100351558; called by muse, mutect2, varscan2
- GBP5 | c.634C>A p.Q212K | Missense Mutation (SNP) | VAF 59/141 reads (42%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV100600170; called by muse, mutect2, varscan2
- GCN1 | c.7728G>T p.W2576C | Missense Mutation (SNP) | VAF 44/527 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as COSV100326011; called by muse, mutect2
- GDF6 | c.1161C>A p.C387* | Nonsense Mutation (SNP) | VAF 11/80 reads (14%) | catalogued as COSV99748571; called by muse, mutect2, varscan2
- GGH | c.209G>C p.R70T | Missense Mutation (SNP) | VAF 28/246 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99479039, COSV99479057; called by muse, varscan2
- GIMAP5 | c.472G>A p.G158S | Missense Mutation (SNP) | VAF 60/295 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.455); catalogued as rs138178760; called by muse, mutect2, varscan2
- GINM1 | c.161G>T p.G54V | Missense Mutation (SNP) | VAF 58/131 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100805373; called by muse, mutect2, varscan2
- GK2 | c.430C>A p.P144T | Missense Mutation (SNP) | VAF 38/220 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100726043; called by muse, mutect2, varscan2
- GLOD4 | c.657C>G p.F219L (on ENST00000301328 / NM_001366247.1; = p.F204L on NM_016080.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/400 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100022821; called by muse, mutect2, varscan2
- GNAT3 | c.319C>A p.L107I | Missense Mutation (SNP) | VAF 62/306 reads (20%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.999); catalogued as rs780587404, COSV101242420; called by muse, mutect2, varscan2
- GOLGB1 | c.6862G>A p.E2288K | Missense Mutation (SNP) | VAF 68/151 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as COSV61463876, COSV61463941; called by muse, mutect2, varscan2
- GPAT3 | c.226G>T p.E76* | Nonsense Mutation (SNP) | VAF 32/166 reads (19%) | catalogued as rs1244789326, COSV100023300; called by muse, mutect2, varscan2
- GPN3 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 16/237 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.166); catalogued as rs1208040516, COSV99959985; called by muse, mutect2
- GPR139 | c.1005C>G p.I335M | Missense Mutation (SNP) | VAF 34/488 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.924); catalogued as COSV58504970; called by muse, mutect2
- GPR158 | c.182G>T p.W61L | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV100894312; called by muse, mutect2, varscan2
- GPR22 | c.950T>A p.L317* | Nonsense Mutation (SNP) | VAF 31/186 reads (17%) | catalogued as COSV99773233; called by muse, mutect2, varscan2
- GPRC6A | c.1586G>T p.G529V | Missense Mutation (SNP) | VAF 42/148 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100114795; called by muse, mutect2, varscan2
- GPRC6A | c.1194G>C p.M398I | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.02); catalogued as COSV100114223, COSV100114798; called by muse, mutect2, varscan2
- GRIA4 | c.1018G>A p.G340S | Missense Mutation (SNP) | VAF 77/158 reads (49%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV99234563; called by muse, mutect2, varscan2
- GRID2 | c.1955T>G p.L652R | Missense Mutation (SNP) | VAF 18/181 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56190673, COSV99943763; called by muse, mutect2
- GRIK1 | c.2709C>A p.N903K (on ENST00000327783 / NM_001330994.2; = p.N859K on NM_175611.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.173); catalogued as COSV100584509; called by muse, mutect2, varscan2
- GRIN2A | c.1556C>G p.S519C | Missense Mutation (SNP) | VAF 111/203 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV100411098; called by muse, mutect2, varscan2
- GRIP2 | c.742C>T p.L248F (on ENST00000619221; = p.L151F on NM_001080423.4) | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99817684; called by muse, mutect2, varscan2
- GRM1 | c.79G>C p.V27L | Missense Mutation (SNP) | VAF 155/314 reads (49%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV99269023; called by muse, mutect2, varscan2
- GRM7 | c.1139G>C p.G380A | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT tolerated (0.67); PolyPhen benign (0.007); catalogued as COSV100738726; called by muse, mutect2
- GYPE | c.71G>A p.G24D | Missense Mutation (SNP) | VAF 102/679 reads (15%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.015); catalogued as rs1273646053, COSV62262121; called by muse, mutect2, varscan2
- H2AC6 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV58416030, COSV58417289; called by muse, mutect2, varscan2
- HAP1 | c.1951G>T p.G651C (on ENST00000310778 / NM_001367460.1; = p.G599C on NM_177977.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/220 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as COSV100170004; called by muse, mutect2, varscan2
- HAUS6 | c.1764G>C p.L588F | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.683); catalogued as COSV65840237; called by muse, mutect2, varscan2
- HBD | c.350G>T p.R117L | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.04); catalogued as CM023082, CM032939, COSV53082154, COSV99496881; called by muse, mutect2, varscan2
- HEATR5A | c.2212G>C p.D738H | Missense Mutation (SNP) | VAF 7/145 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV101120569; called by muse, mutect2
- HECW1 | c.1402G>T p.A468S | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as COSV101224320; called by muse, mutect2
- HIRA | c.1624A>G p.T542A | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV99600024; called by muse, mutect2, varscan2
- HLTF | c.61G>T p.V21F | Missense Mutation (SNP) | VAF 30/153 reads (20%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.121); catalogued as COSV100027149; called by muse, mutect2, varscan2
- HMGCL | c.750G>T p.Q250H | Missense Mutation (SNP) | VAF 50/136 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52525712, COSV99354108; called by muse, mutect2, varscan2
- HOXD12 | c.47T>C p.L16P | Missense Mutation (SNP) | VAF 101/197 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101184356; called by muse, mutect2, varscan2
- HRNR | c.7068G>C p.Q2356H | Missense Mutation (SNP) | VAF 88/2073 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV100912871, COSV100913970; called by muse, mutect2
- HSPA6 | c.1605G>T p.R535S | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.633); catalogued as COSV100553860; called by muse, mutect2, varscan2
- HTR1E | c.508C>A p.P170T | Missense Mutation (SNP) | VAF 88/155 reads (57%) | SIFT tolerated (0.57); PolyPhen benign (0.158); catalogued as rs760216096, COSV100541310; called by muse, mutect2, varscan2
- HTRA3 | c.934C>A p.L312M | Missense Mutation (SNP) | VAF 46/113 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100246545; called by muse, mutect2, varscan2
- ICAM1 | c.443T>C p.V148A | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.634); catalogued as COSV99321164; called by muse, mutect2, varscan2
- IGF1R | c.761A>T p.Y254F | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV99163112; called by muse, mutect2, varscan2
- IGF2BP3 | c.913G>T p.D305Y | Missense Mutation (SNP) | VAF 39/268 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.114); catalogued as rs375047828; called by muse, mutect2, varscan2
- IGSF21 | c.161T>C p.M54T | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.12); catalogued as COSV99246260; called by muse, mutect2, varscan2
- INSM1 | c.1423C>A p.P475T | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100044884; called by muse, mutect2, varscan2
- IQGAP1 | c.231C>A p.Y77* | Nonsense Mutation (SNP) | VAF 12/110 reads (11%) | catalogued as COSV99185371; called by muse, varscan2
- IRAK4 | c.942-1G>T p.X314_splice | Splice Site (SNP) | VAF 7/88 reads (8%) | catalogued as COSV101471847; called by muse, mutect2
- ITIH1 | c.2591G>A p.R864Q | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT tolerated (0.62); PolyPhen benign (0.011); catalogued as rs913144777, COSV56257882; called by muse, mutect2, varscan2
- ITPRIPL1 | c.1324C>A p.P442T (on ENST00000439118 / NM_001008949.3; = p.P450T on NM_178495.6) | Missense Mutation (SNP) | VAF 113/208 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.651); catalogued as COSV100742246; called by muse, mutect2, varscan2
- JAKMIP1 | c.724G>C p.A242P | Missense Mutation (SNP) | VAF 19/270 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV99290825; called by muse, mutect2
- JAKMIP3 | c.194A>T p.Q65L | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.415); catalogued as COSV100059954; called by muse, mutect2, varscan2
- JHY | c.680C>T p.P227L | Missense Mutation (SNP) | VAF 13/226 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV56218965; called by muse, mutect2
- JPH2 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65906320; called by muse, mutect2, varscan2
- KANSL1 | c.3218G>A p.R1073Q (on ENST00000574590 / NM_001193465.2; = p.R1074Q on NM_015443.4) | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.71); catalogued as rs763541067, COSV52239430, COSV99290010; ClinVar: likely benign; called by muse, mutect2, varscan2
- KCNA6 | c.157G>C p.E53Q | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as COSV99768985; called by muse, mutect2, varscan2
- KCNA6 | c.604G>C p.D202H | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.067); catalogued as COSV54974347, COSV99768987; called by muse, mutect2, varscan2
- KCNH1 | c.2390C>A p.P797H (on ENST00000271751 / NM_172362.3; = p.P770H on NM_002238.4) | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV99661555; called by muse, mutect2, varscan2
- KCNH7 | c.3053G>C p.G1018A | Missense Mutation (SNP) | VAF 132/356 reads (37%) | SIFT tolerated (0.53); PolyPhen benign (0.152); catalogued as COSV100149875; called by muse, mutect2, varscan2
- KCNJ1 | c.1060C>T p.H354Y | Missense Mutation (SNP) | VAF 28/142 reads (20%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as COSV100131485, COSV60662819; called by muse, mutect2, varscan2
- KCNK18 | c.601C>T p.Q201* | Nonsense Mutation (SNP) | VAF 32/111 reads (29%) | catalogued as COSV100572143; called by muse, mutect2, varscan2
- KCNK2 | c.103C>A p.L35I (on ENST00000444842 / NM_001017425.3; = p.L20I on NM_014217.4) | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV101222340; called by muse, mutect2, varscan2
- KCNT2 | c.675G>C p.K225N | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV54074877, COSV54098825, COSV99656794; called by muse, mutect2, varscan2
- KCNT2 | c.68G>T p.G23V | Missense Mutation (SNP) | VAF 23/205 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.911); catalogued as rs1430731293, COSV54064698, COSV54069570; called by muse, mutect2, varscan2
- KCNV1 | c.913G>C p.E305Q | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT tolerated (1); PolyPhen possibly damaging (0.903); catalogued as COSV99819450; called by muse, mutect2, varscan2
- KDM4D | c.421A>G p.S141G | Missense Mutation (SNP) | VAF 26/190 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as COSV100624365; called by muse, mutect2, varscan2
- KDM7A | c.2284G>A p.E762K | Missense Mutation (SNP) | VAF 18/240 reads (8%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV99135157; called by muse, mutect2
- KHDRBS2 | c.134A>G p.E45G | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV99837658; called by muse, mutect2, varscan2
- KHDRBS3 | c.202C>A p.P68T | Missense Mutation (SNP) | VAF 14/190 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100879021, COSV63417693; called by muse, mutect2
- KIAA1549L | c.2257A>T p.T753S (on ENST00000321505; = p.T1050S on NM_012194.3) | Missense Mutation (SNP) | VAF 51/170 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as COSV99684471; called by muse, mutect2, varscan2
- KIAA1614 | c.2789C>A p.A930E | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs868559558, COSV62551587; called by muse, mutect2, varscan2
- KIAA1841 | c.431G>T p.G144V | Missense Mutation (SNP) | VAF 42/77 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV99694232; called by muse, mutect2, varscan2
- KIAA1958 | c.1552A>T p.S518C | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.408); catalogued as COSV100516484; called by muse, mutect2
- KIF14 | c.2663T>C p.V888A | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100951089; called by muse, mutect2, varscan2
- KIF1A | c.2153A>T p.Q718L | Missense Mutation (SNP) | VAF 60/99 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV100242375; called by muse, mutect2, varscan2
- KIF20B | c.1388A>G p.Y463C | Missense Mutation (SNP) | VAF 44/162 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.81); catalogued as rs770205047, COSV99590745; called by muse, mutect2, varscan2
- KIF21B | c.4591C>A p.L1531I (on ENST00000422435 / NM_001252100.2; = p.L1518I on NM_017596.4) | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.76); catalogued as COSV100145157; called by muse, mutect2, varscan2
- KIF27 | c.564G>T p.M188I | Missense Mutation (SNP) | VAF 80/360 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.051); catalogued as COSV52829455; called by muse, mutect2, varscan2
- KMT2E | c.3058G>C p.V1020L | Missense Mutation (SNP) | VAF 12/206 reads (6%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as COSV57572056, COSV99997034; called by muse, mutect2
- KMT5A | c.895C>G p.H299D | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100389621; called by muse, mutect2, varscan2
- KRT75 | c.1574G>T p.S525I | Missense Mutation (SNP) | VAF 32/270 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); catalogued as COSV99359655; called by muse, mutect2, varscan2
- KRTAP15-1 | c.35C>A p.S12Y | Missense Mutation (SNP) | VAF 19/162 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100481664; called by muse, mutect2
- KRTAP6-2 | c.140G>T p.R47L | Missense Mutation (SNP) | VAF 6/49 reads (12%) | PolyPhen benign (0.346); catalogued as COSV100588942; called by mutect2, varscan2
- KRTAP9-2 | c.149C>G p.P50R | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as COSV100893252; called by muse, varscan2
- LDB3 | c.419C>A p.P140H | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV99555896; called by muse, mutect2, varscan2
- LIPI | c.1352C>A p.P451Q | Missense Mutation (SNP) | VAF 60/277 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100754023; called by muse, mutect2, varscan2
- LMBR1 | c.986G>T p.G329V | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV100626857; called by muse, mutect2, varscan2
- LMO7 | c.3115G>C p.D1039H (on ENST00000357063; = p.D720H on NM_005358.5) | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100413868; called by muse, mutect2, varscan2
- LRCH2 | c.2009C>A p.A670D | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100407580; called by muse, mutect2, varscan2
- LRP12 | c.2339C>A p.S780Y | Missense Mutation (SNP) | VAF 55/307 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.641); catalogued as COSV99408376; called by muse, mutect2, varscan2
- LRP1B | c.6226G>T p.E2076* | Nonsense Mutation (SNP) | VAF 32/217 reads (15%) | catalogued as COSV101261240, COSV67197518; called by muse, mutect2, varscan2
- LRRC58 | c.745G>T p.V249F | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99820292; called by muse, mutect2, varscan2
- LRRC66 | c.1645A>T p.S549C | Missense Mutation (SNP) | VAF 499/632 reads (79%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.667); catalogued as COSV100603109; called by muse, mutect2, varscan2
- LRRN3 | c.947C>A p.A316D | Missense Mutation (SNP) | VAF 120/243 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100073081, COSV100073732; called by muse, mutect2, varscan2
- LTBP1 | c.3151G>T p.G1051C (on ENST00000404816 / NM_206943.4; = p.G725C on NM_000627.4) | Missense Mutation (SNP) | VAF 60/96 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99698436; called by muse, mutect2, varscan2
- LTBP3 | c.1423G>A p.E475K | Missense Mutation (SNP) | VAF 25/205 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.119); catalogued as rs1199471046, COSV100100407; called by muse, mutect2, varscan2
- LYNX1-SLURP2 | c.346C>A p.P116T | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100235831; called by muse, mutect2, varscan2
- LYNX1-SLURP2 | c.242G>A p.C81Y | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV58186422; called by muse, mutect2, varscan2
- LYPD6B | c.136A>T p.N46Y (on ENST00000409029 / NM_001317004.1; = p.N70Y on NM_177964.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 86/492 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as COSV99700457; called by muse, mutect2, varscan2
- LYZL1 | c.56C>A p.S19Y | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs750632053, COSV100973684; called by muse, mutect2, varscan2
- MAGEB10 | c.780C>A p.Y260* | Nonsense Mutation (SNP) | VAF 12/46 reads (26%) | catalogued as COSV100775414; called by muse, mutect2, varscan2
- MAGI1 | c.1997A>T p.Q666L | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as COSV100443161; called by muse, mutect2
- MAGI2 | c.3337G>T p.D1113Y | Missense Mutation (SNP) | VAF 64/326 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100836646, COSV62652770; called by muse, mutect2, varscan2
- MAP3K12 | c.536T>A p.V179E | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57236957, COSV99913565; called by muse, mutect2, varscan2
- MARCHF11 | c.931C>A p.R311S | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100198278, COSV60126013, COSV60127080; called by muse, mutect2, varscan2
- MARCHF7 | c.1682C>T p.S561L | Missense Mutation (SNP) | VAF 29/212 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99374139; called by muse, mutect2, varscan2
- MARK1 | c.1249C>G p.Q417E | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as COSV100857571; called by muse, mutect2, varscan2
- MCF2 | c.290C>T p.A97V | Missense Mutation (SNP) | VAF 85/246 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as COSV100645178; called by muse, mutect2, varscan2
- MDC1 | c.5224T>C p.C1742R | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.093); catalogued as COSV100903093; called by muse, mutect2, varscan2
- MED13 | c.1383G>T p.K461N | Missense Mutation (SNP) | VAF 45/114 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101181412; called by muse, mutect2, varscan2
- MED13L | c.6110A>T p.N2037I | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99930202; called by muse, mutect2, varscan2
- MGA | c.1051G>T p.E351* | Nonsense Mutation (SNP) | VAF 14/37 reads (38%) | catalogued as COSV54966642, COSV99581610; called by muse, mutect2, varscan2
- MID1 | c.214G>T p.G72W | Missense Mutation (SNP) | VAF 46/208 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100452217; called by muse, mutect2, varscan2
- MINAR1 | c.2728C>A p.P910T | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100549284; called by muse, mutect2, varscan2
- MMP17 | c.178G>T p.G60C | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100861980, COSV62179596; called by muse, mutect2, varscan2
- MMP21 | c.1453T>A p.Y485N | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as COSV100524032; called by muse, mutect2, varscan2
- MOV10L1 | c.3466C>A p.P1156T | Missense Mutation (SNP) | VAF 49/236 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV99435184; called by muse, mutect2, varscan2
- MROH2B | c.2432G>A p.R811K | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.98); catalogued as COSV101270684, COSV101270931; called by muse, varscan2
- MROH8 | c.1970G>T p.R657I | Missense Mutation (SNP) | VAF 64/493 reads (13%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.136); catalogued as COSV99457950; called by muse, mutect2, varscan2
- MRPL32 | c.244A>T p.K82* | Nonsense Mutation (SNP) | VAF 71/167 reads (43%) | catalogued as COSV99786036; called by muse, mutect2, varscan2
- MS4A6A | c.649G>T p.G217W | Missense Mutation (SNP) | VAF 32/224 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.27); catalogued as COSV100125112; called by muse, mutect2, varscan2
- MSH4 | c.1231-2A>G p.X411_splice | Splice Site (SNP) | VAF 15/134 reads (11%) | catalogued as COSV99592564; called by muse, mutect2, varscan2
- MTERF3 | c.1223A>T p.Q408L | Missense Mutation (SNP) | VAF 7/174 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV99749302; called by muse, mutect2
- MUC16 | c.36299A>T p.N12100I | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.835); catalogued as rs770309663, COSV101201754; called by muse, mutect2, varscan2
- MUC16 | c.35759C>A p.T11920K | Missense Mutation (SNP) | VAF 72/159 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.943); catalogued as rs953542154, COSV101201755; called by muse, mutect2, varscan2
- MUC16 | c.31778C>A p.P10593Q | Missense Mutation (SNP) | VAF 64/136 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as COSV101201757; called by muse, mutect2, varscan2
- MUC16 | c.8732G>T p.G2911V | Missense Mutation (SNP) | VAF 46/79 reads (58%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.657); catalogued as COSV101201759; called by muse, mutect2, varscan2
- MUC16 | c.8731G>T p.G2911* | Nonsense Mutation (SNP) | VAF 46/79 reads (58%) | catalogued as COSV101200591, COSV101201760; called by muse, mutect2, varscan2
- MUC7 | c.143A>T p.Y48F | Missense Mutation (SNP) | VAF 28/198 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.048); catalogued as COSV100512388; called by muse, mutect2, varscan2
- MYBPC2 | c.1996G>T p.G666W | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756397342, COSV100732028; called by muse, mutect2, varscan2
- MYH13 | c.1562C>G p.A521G | Missense Mutation (SNP) | VAF 55/129 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.374); catalogued as COSV99355494; called by muse, mutect2, varscan2
- MYH3 | c.326G>A p.R109H | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs773615398, COSV56860673; called by muse, mutect2, varscan2
- MYO16 | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 24/289 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.184); catalogued as rs1180371269, COSV99194664; called by muse, mutect2
- MYO18B | c.5820G>C p.K1940N | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.019); catalogued as COSV100125235; called by mutect2, varscan2
- MYO3A | c.2665G>T p.V889F | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.148); catalogued as rs1337564123, COSV99781645; called by muse, mutect2, varscan2
- MYO5A | c.3778G>T p.D1260Y | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.238); catalogued as COSV100698182; called by muse, mutect2, varscan2
- MYOCD | c.1527G>T p.E509D | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV100591445; called by muse, mutect2, varscan2
- MYOF | c.3766G>T p.G1256* | Nonsense Mutation (SNP) | VAF 41/160 reads (26%) | catalogued as COSV100826134; called by muse, mutect2, varscan2
- NAF1 | c.718-1G>C p.X240_splice | Splice Site (SNP) | VAF 22/205 reads (11%) | catalogued as COSV99919396; called by muse, mutect2
- NAPB | c.358G>T p.A120S | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.919); catalogued as COSV100986015; called by muse, mutect2, varscan2
- NAV3 | c.2179G>T p.G727* | Nonsense Mutation (SNP) | VAF 55/143 reads (38%) | catalogued as COSV99894367; called by muse, mutect2, varscan2
- NAV3 | c.4366G>C p.G1456R | Missense Mutation (SNP) | VAF 40/207 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV99895804; called by muse, mutect2, varscan2
- NAV3 | c.4367G>T p.G1456V | Missense Mutation (SNP) | VAF 43/213 reads (20%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as COSV99895808; called by muse, mutect2, varscan2
- NDUFS1 | c.1351A>C p.I451L | Missense Mutation (SNP) | VAF 8/209 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV99261496; called by muse, mutect2
- NDUFS7 | c.434G>T p.R145L | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as CM071884, COSV99282606, COSV99283023; called by muse, mutect2, varscan2
- NEGR1 | c.823A>T p.N275Y | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100166137, COSV100166233; called by muse, mutect2, varscan2
- NEK5 | c.1075G>T p.D359Y | Missense Mutation (SNP) | VAF 51/139 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as rs77133890, COSV100839167, COSV100839306; called by muse, mutect2, varscan2
- NELL1 | c.966C>A p.H322Q | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as COSV100125333; called by muse, mutect2, varscan2
- NIN | c.2024A>T p.E675V | Missense Mutation (SNP) | VAF 46/270 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs369112110, COSV99815321; called by muse, mutect2, varscan2
- NLGN4X | c.421G>C p.D141H | Missense Mutation (SNP) | VAF 48/240 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.066); catalogued as COSV99323987; called by muse, mutect2, varscan2
- NLRC3 | c.839T>C p.V280A | Missense Mutation (SNP) | VAF 124/182 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100073430; called by muse, mutect2, varscan2
- NPR1 | c.590T>G p.F197C | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100903820; called by muse, varscan2
- NPSR1 | c.662T>C p.I221T | Missense Mutation (SNP) | VAF 46/190 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV100707188; called by muse, mutect2, varscan2
- NR4A2 | c.1706G>T p.G569V | Missense Mutation (SNP) | VAF 64/137 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100277392; called by muse, mutect2, varscan2
- NR4A2 | c.1705G>T p.G569W | Missense Mutation (SNP) | VAF 63/137 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59894582; called by muse, mutect2, varscan2
- NRAP | c.4505G>A p.R1502Q (on ENST00000359988 / NM_001322945.2; = p.R1467Q on NM_006175.4) | Missense Mutation (SNP) | VAF 61/217 reads (28%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.986); catalogued as rs751856343, COSV63488845; called by muse, mutect2, varscan2
- NRXN1 | c.1922T>A p.V641E | Missense Mutation (SNP) | VAF 101/248 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100456930; called by muse, mutect2, varscan2
- NRXN1 | c.1399G>T p.G467* | Nonsense Mutation (SNP) | VAF 121/230 reads (53%) | catalogued as COSV100456931; called by muse, mutect2, varscan2
- NRXN2 | c.972C>A p.N324K | Missense Mutation (SNP) | VAF 33/161 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99635857; called by muse, mutect2, varscan2
- NRXN3 | c.1197C>G p.N399K (on ENST00000335750 / NM_001330195.2; = p.N26K on NM_004796.6) | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100209243; called by muse, mutect2, varscan2
- NRXN3 | c.2440G>A p.E814K (on ENST00000335750 / NM_001330195.2; = p.E441K on NM_004796.6) | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59787117; called by muse, mutect2, varscan2
- NTNG1 | c.783C>A p.D261E | Missense Mutation (SNP) | VAF 52/103 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99639569; called by muse, mutect2, varscan2
- NUCKS1 | c.397G>T p.D133Y | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100900808, COSV65652813; called by muse, mutect2, varscan2
- NUDT3 | c.127C>G p.P43A | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV101657174; called by muse, mutect2
- NUP133 | c.2264C>G p.S755* | Nonsense Mutation (SNP) | VAF 44/249 reads (18%) | catalogued as COSV99773489; called by muse, mutect2, varscan2
- NUP205 | c.5224A>T p.K1742* | Nonsense Mutation (SNP) | VAF 49/229 reads (21%) | catalogued as COSV99607624; called by muse, mutect2, varscan2
- OBSL1 | c.1744G>T p.V582L | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.299); catalogued as COSV99217524; called by muse, mutect2, varscan2
- OPN5 | c.890C>A p.S297Y | Missense Mutation (SNP) | VAF 170/291 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99790050; called by muse, mutect2, varscan2
- OPRL1 | c.499G>T p.A167S | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100402283; called by muse, mutect2, varscan2
- OR2A14 | c.791G>C p.R264P | Missense Mutation (SNP) | VAF 167/363 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as rs1348857159, COSV101376449, COSV101376499; called by muse, mutect2, varscan2
- OR2B3 | c.764C>A p.A255D | Missense Mutation (SNP) | VAF 62/109 reads (57%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.745); catalogued as COSV65850848; called by muse, mutect2, varscan2
- OR2T2 | c.9G>T p.M3I | Missense Mutation (SNP) | VAF 35/186 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.116); catalogued as COSV100737803, COSV61617916; called by muse, varscan2
- OR4A5 | c.203A>G p.D68G | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.452); catalogued as COSV100157311; called by muse, mutect2, varscan2
- OR4C15 | c.920G>T p.C307F (on ENST00000314644; = p.C253F on NM_001001920.2) | Missense Mutation (SNP) | VAF 91/389 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs143375710, COSV100116111; called by muse, mutect2, varscan2
- OR4C6 | c.688G>A p.G230R | Missense Mutation (SNP) | VAF 80/270 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); catalogued as rs1565078863, COSV58602789; called by muse, varscan2
- OR51F1 | c.238C>A p.L80M | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.178); catalogued as COSV100598913, COSV58580296; called by muse, mutect2, varscan2
- OR52E4 | c.704G>A p.R235Q | Missense Mutation (SNP) | VAF 94/232 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.377); catalogued as rs141226100; called by muse, mutect2, varscan2
- OR52E6 | c.227C>T p.S76F | Missense Mutation (SNP) | VAF 82/165 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs1418790985, COSV100259560; called by muse, mutect2, varscan2
- OR52K2 | c.905G>T p.R302L | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.187); catalogued as COSV100355856; called by muse, mutect2, varscan2
- OR5AC2 | c.461G>T p.G154V | Missense Mutation (SNP) | VAF 154/347 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774695351, COSV100684498, COSV100684500; called by muse, mutect2, varscan2
- OR5D18 | c.307T>C p.F103L | Missense Mutation (SNP) | VAF 59/520 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as rs766348974, COSV100450906; called by muse, mutect2, varscan2
- OR5F1 | c.127C>A p.L43I | Missense Mutation (SNP) | VAF 42/123 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs372205796, COSV53547736; called by muse, mutect2, varscan2
- OR5H2 | c.608T>A p.M203K | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV100788837; called by muse, mutect2, varscan2
- OR5K4 | c.645G>C p.L215F | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.25); catalogued as COSV100721407; called by muse, mutect2, varscan2
- OR6F1 | c.710C>A p.A237D | Missense Mutation (SNP) | VAF 47/155 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57467415; called by muse, mutect2, varscan2
- OR9A2 | c.673C>T p.P225S | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.21); catalogued as rs1409835636, COSV63306655; called by muse, mutect2, varscan2
- OR9Q2 | c.931G>T p.A311S | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100285541, COSV61111885; called by muse, mutect2, varscan2
- OTOL1 | c.491G>T p.G164V | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100020270, COSV60008373; called by muse, mutect2, varscan2
- OTX1 | c.56G>T p.G19V | Missense Mutation (SNP) | VAF 89/161 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.416); catalogued as COSV56995661; called by muse, mutect2, varscan2
- OVCH1 | c.1700G>T p.S567I | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); catalogued as COSV100549233; called by muse, mutect2, varscan2
- PATJ | c.2546A>T p.E849V | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100334993; called by muse, mutect2, varscan2
- PCDH15 | c.5834A>T p.E1945V | Missense Mutation (SNP) | VAF 17/196 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.601); catalogued as COSV100227837, COSV57342026; called by muse, mutect2
- PCDH17 | c.2926C>A p.P976T | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.724); catalogued as COSV100932055; called by muse, mutect2
- PCDH9 | c.725T>G p.V242G | Missense Mutation (SNP) | VAF 42/150 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100123611; called by muse, mutect2, varscan2
- PCDHA9 | c.1951G>T p.V651L | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.914); catalogued as COSV65331603; called by muse, mutect2, varscan2
- PCDHB2 | c.1036C>A p.P346T | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.015); catalogued as COSV50564267, COSV99166694; called by muse, mutect2, varscan2
- PCDHGA2 | c.854C>A p.P285H | Missense Mutation (SNP) | VAF 95/230 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.033); catalogued as COSV54048839, COSV99547239; called by muse, mutect2, varscan2
- PCDHGA4 | c.2408A>C p.Q803P | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99547240; called by muse, mutect2, varscan2
- PCDHGA7 | c.2196G>T p.L732F | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.039); catalogued as COSV99547241; called by muse, mutect2, varscan2
- PCDHGA9 | c.271G>T p.D91Y | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99547245; called by muse, mutect2, varscan2
- PCSK5 | c.4385A>T p.D1462V | Missense Mutation (SNP) | VAF 27/211 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); catalogued as COSV101377713; called by muse, mutect2, varscan2
- PDCD10 | c.598C>G p.Q200E | Missense Mutation (SNP) | VAF 18/248 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as CM143716, COSV101208510; called by muse, mutect2
- PDE11A | c.2765_2766insA p.A923Cfs*26 | Frame Shift Ins (INS) | VAF 119/205 reads (58%) | catalogued as COSV53703144; called by mutect2, varscan2*
- PDE3A | c.580G>C p.V194L | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV100762815; called by muse, mutect2, varscan2
- PDP1 | c.853C>T p.H285Y | Missense Mutation (SNP) | VAF 26/191 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.136); catalogued as COSV99892981; called by muse, mutect2, varscan2
- PDZRN3 | c.2909G>T p.G970V | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99732158; called by muse, mutect2, varscan2
- PDZRN3 | c.1357G>C p.D453H | Missense Mutation (SNP) | VAF 47/120 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99732162; called by muse, mutect2, varscan2
- PDZRN4 | c.2322C>A p.S774R (on ENST00000402685 / NM_001164595.2; = p.S516R on NM_013377.4) | Missense Mutation (SNP) | VAF 17/162 reads (10%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.544); catalogued as COSV100115500; called by muse, mutect2, varscan2
- PEAK1 | c.102G>T p.E34D | Missense Mutation (SNP) | VAF 44/196 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.116); catalogued as COSV100433451; called by muse, mutect2, varscan2
- PEG10 | c.152C>A p.T51N (on ENST00000482108 / NM_001040152.2; = p.T85N on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.006); catalogued as COSV101509977; called by muse, mutect2
- PEG3 | c.1896T>A p.C632* | Nonsense Mutation (SNP) | VAF 41/134 reads (31%) | catalogued as COSV99687388, COSV99690425; called by muse, mutect2, varscan2
- PEX1 | c.319G>C p.E107Q | Missense Mutation (SNP) | VAF 17/238 reads (7%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.965); catalogued as COSV99952377; called by muse, mutect2
- PFKL | c.1366G>T p.A456S | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.048); catalogued as COSV100827303; called by muse, mutect2, varscan2
- PGAP6 | c.532G>A p.V178I | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as rs1401306557, COSV99170802; called by muse, mutect2
- PIK3R4 | c.2937G>T p.W979C | Missense Mutation (SNP) | VAF 64/156 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764488338, COSV100768600; called by muse, mutect2, varscan2
- PIK3R5 | c.35G>T p.R12L | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs779999550; called by muse, mutect2
- PIK3R5 | c.34C>A p.R12S | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99353893; called by muse, mutect2, varscan2
- PJA1 | c.1895G>A p.C632Y (on ENST00000361478 / NM_145119.4; = p.C444Y on NM_022368.5) | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100824817; called by muse, mutect2, varscan2
- PKHD1L1 | c.1742A>T p.D581V | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.724); catalogued as COSV101006851; called by muse, mutect2
- PKHD1L1 | c.3281C>G p.P1094R | Missense Mutation (SNP) | VAF 242/992 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as COSV101006852, COSV65756081; called by muse, mutect2, varscan2
- PKP2 | c.1506A>T p.Q502H | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.216); catalogued as COSV99298505; called by muse, mutect2, varscan2
- PLCH1 | c.3371C>G p.S1124* (on ENST00000340059 / NM_001130960.2; = p.S1116* on NM_014996.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 29/143 reads (20%) | catalogued as COSV100395521; called by muse, mutect2, varscan2
- PLEKHA5 | c.541A>G p.S181G | Missense Mutation (SNP) | VAF 206/467 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100164768; called by muse, mutect2, varscan2
- PLS1 | c.1528G>T p.D510Y | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV100538361; called by muse, mutect2, varscan2
- PLXDC2 | c.1516T>C p.S506P | Missense Mutation (SNP) | VAF 17/168 reads (10%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.996); catalogued as rs1309138543, COSV101023283; called by muse, mutect2
- PLXNA1 | c.4484G>T p.R1495L | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99304132; called by muse, mutect2, varscan2
- PLXNA4 | c.5226C>T p.C1742= | Splice Region (SNP) | VAF 60/132 reads (45%) | catalogued as rs781501987, COSV100327187, COSV58151795; called by muse, mutect2, varscan2
- PLXNA4 | c.3190C>A p.H1064N | Missense Mutation (SNP) | VAF 29/183 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100327188; called by muse, mutect2, varscan2
- PLXNA4 | c.688C>A p.P230T | Missense Mutation (SNP) | VAF 37/169 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100327191; called by muse, mutect2, varscan2
- PNPLA8 | c.1295G>T p.G432V | Missense Mutation (SNP) | VAF 24/205 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99993825; called by muse, mutect2, varscan2
- POLR3A | c.1546A>G p.K516E | Missense Mutation (SNP) | VAF 77/217 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV100965803; called by muse, mutect2, varscan2
- POLR3B | c.3111A>T p.E1037D | Missense Mutation (SNP) | VAF 34/154 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV99943869; called by muse, mutect2, varscan2
- POMK | c.30A>T p.R10S | Missense Mutation (SNP) | VAF 48/164 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV100505986; called by muse, mutect2, varscan2
- POSTN | c.1133G>T p.G378V | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV101123500, COSV101123530; called by muse, mutect2, varscan2
- POSTN | c.1132G>T p.G378* | Nonsense Mutation (SNP) | VAF 28/58 reads (48%) | catalogued as COSV101123501; called by muse, mutect2, varscan2
- POTED | c.211T>C p.C71R | Missense Mutation (SNP) | VAF 61/141 reads (43%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.384); catalogued as COSV100203240; called by muse, mutect2, varscan2
- PPARGC1A | c.1889G>A p.R630H | Missense Mutation (SNP) | VAF 21/191 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs372413128; called by muse, mutect2, varscan2
- PPEF2 | c.918A>C p.K306N | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.984); catalogued as COSV99715010; called by muse, mutect2, varscan2
- PPP1R3A | c.1948C>A p.P650T | Missense Mutation (SNP) | VAF 149/336 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99494341; called by muse, mutect2, varscan2
- PPP3CA | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 23/187 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100547878, COSV100548159; called by muse, mutect2, varscan2
- PRAMEF20 | c.1139C>A p.T380N | Missense Mutation (SNP) | VAF 189/410 reads (46%) | SIFT tolerated (0.3); PolyPhen benign (0.024); catalogued as rs1007127222, COSV57081511; called by muse, mutect2, varscan2
- PRDM14 | c.841G>C p.G281R | Missense Mutation (SNP) | VAF 46/244 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99400531; called by muse, mutect2, varscan2
- PRELID3B | c.257C>T p.P86L | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.679); catalogued as COSV99718219; called by muse, mutect2, varscan2
- PRG4 | c.2293C>A p.P765T | Missense Mutation (SNP) | VAF 72/190 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs199791520; called by muse, varscan2
- PRKCB | c.280G>T p.A94S | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as COSV100335420; called by muse, mutect2, varscan2
- PRKG2 | c.566A>G p.Y189C | Missense Mutation (SNP) | VAF 58/198 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.127); catalogued as rs752074471, COSV100020565; called by muse, mutect2, varscan2
- PRKX | c.239T>A p.M80K | Missense Mutation (SNP) | VAF 58/149 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV53323086, COSV99468596; called by muse, mutect2, varscan2
- PRMT7 | c.1612G>A p.E538K | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1449167583, COSV99546075; called by muse, mutect2
- PROX1 | c.1190G>T p.G397V | Missense Mutation (SNP) | VAF 25/160 reads (16%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.935); catalogued as COSV54778077; called by muse, mutect2, varscan2
- PRPF40B | c.1328A>G p.N443S (on ENST00000380281; = p.N437S on NM_012272.3) | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as COSV99980171; called by muse, mutect2
- PRPF6 | c.2208G>A p.L736= | Splice Region (SNP) | VAF 32/383 reads (8%) | catalogued as COSV99412852; called by muse, mutect2
- PRSS53 | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs748276565, COSV99762675; called by muse, mutect2, varscan2
- PRUNE2 | c.5716C>A p.Q1906K | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1175953536, COSV100945154; called by muse, mutect2, varscan2
- PTPRB | c.3478del p.E1160Sfs*17 | Frame Shift Del (DEL) | VAF 17/131 reads (13%) | catalogued as COSV54252129; called by mutect2, pindel, varscan2
- PTPRC | c.3826G>A p.E1276K | Missense Mutation (SNP) | VAF 41/133 reads (31%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as COSV100723206; called by muse, mutect2, varscan2
- PTPRM | c.3635G>T p.R1212L | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100155194, COSV100157544; called by muse, mutect2, varscan2
- PTPRO | c.2557A>T p.R853W | Missense Mutation (SNP) | VAF 60/144 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99841773; called by muse, mutect2, varscan2
- PTPRT | c.3161G>A p.G1054D | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV62023487; called by muse, mutect2, varscan2
- PTPRZ1 | c.1694T>A p.I565K | Missense Mutation (SNP) | VAF 39/149 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.024); catalogued as COSV101100865, COSV66438834; called by muse, mutect2, varscan2
- PTPRZ1 | c.3634C>T p.P1212S | Missense Mutation (SNP) | VAF 46/508 reads (9%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.01); catalogued as COSV66437083; called by muse, mutect2
- PTX4 | c.1142G>A p.R381K (on ENST00000447419 / NM_001328608.2; = p.R376K on NM_001013658.1) | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.298); catalogued as COSV99560796; called by muse, mutect2, varscan2
- PXDNL | c.2089C>A p.P697T | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as COSV99080570; called by muse, mutect2, varscan2
- RAB7A | c.302G>T p.S101I | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.1); catalogued as COSV99414187, COSV99414336; called by muse, mutect2, varscan2
- RAG1 | c.356G>T p.R119I | Missense Mutation (SNP) | VAF 59/139 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.053); catalogued as rs901852177, COSV100201173; called by muse, mutect2, varscan2
- RB1CC1 | c.1132A>T p.S378C | Missense Mutation (SNP) | VAF 61/158 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99213010; called by muse, mutect2, varscan2
- RBL2 | c.2397G>T p.L799F | Missense Mutation (SNP) | VAF 54/108 reads (50%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.521); catalogued as COSV100044069; called by muse, mutect2, varscan2
- RBM19 | c.1979G>T p.G660V | Missense Mutation (SNP) | VAF 55/152 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as COSV99926845; called by muse, mutect2
- RBM33 | c.965C>T p.P322L | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.79); PolyPhen benign (0.372); catalogued as rs1399806678, COSV100265749; called by muse, mutect2, varscan2
- REST | c.833G>T p.C278F | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100471352; called by muse, mutect2, varscan2
- RFX3 | c.1552C>T p.Q518* | Nonsense Mutation (SNP) | VAF 46/287 reads (16%) | catalogued as COSV100175882; called by muse, mutect2, varscan2
- RIPK4 | c.1825G>T p.V609L (on ENST00000352483; = p.V561L on NM_020639.3) | Missense Mutation (SNP) | VAF 64/100 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as CM161275, COSV100205397; called by muse, mutect2, varscan2
- ROBO4 | c.2693G>T p.G898V | Missense Mutation (SNP) | VAF 54/84 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100127871; called by muse, mutect2, varscan2
- ROCK1 | c.1736A>G p.E579G | Missense Mutation (SNP) | VAF 39/318 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV101296628; called by muse, mutect2, varscan2
- RPL22L1 | c.365A>T p.D122V | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as COSV99860642; called by muse, mutect2, varscan2
- RPL22L1 | c.274G>T p.D92Y | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99860644; called by muse, mutect2, varscan2
- RPS6KA2 | c.308G>A p.R103Q | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs749147718, COSV55826267, COSV99692157; called by muse, mutect2, varscan2
- RRAGD | c.931T>A p.Y311N | Missense Mutation (SNP) | VAF 123/200 reads (62%) | SIFT tolerated (0.13); PolyPhen benign (0.374); catalogued as COSV100784651; called by muse, mutect2, varscan2
- RRAS | c.260A>T p.Q87L | Missense Mutation (SNP) | VAF 42/72 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99882135; called by muse, mutect2, varscan2
- RRP12 | c.3177G>T p.E1059D | Missense Mutation (SNP) | VAF 85/318 reads (27%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV100213505; called by muse, mutect2, varscan2
- RSRC1 | c.988G>T p.G330C | Missense Mutation (SNP) | VAF 39/250 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV99907189; called by muse, mutect2, varscan2
- RTL9 | c.2330C>T p.P777L | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.034); catalogued as COSV101511801, COSV71826854; called by muse, mutect2, varscan2
- RTP2 | c.307C>T p.R103W | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV64079258; called by muse, mutect2, varscan2
- RUNX1T1 | c.1777C>A p.P593T (on ENST00000265814 / NM_001198628.1; = p.P566T on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV99755004; called by muse, mutect2, varscan2
- RYR1 | c.5276G>T p.R1759L | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.094); catalogued as COSV100613973, COSV100617045; called by muse, mutect2, varscan2
- RYR2 | c.7234G>T p.G2412W | Missense Mutation (SNP) | VAF 79/240 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100772934, COSV63696306; called by muse, mutect2, varscan2
- RYR2 | c.10504G>A p.E3502K | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.57); catalogued as COSV63684412; called by muse, mutect2
- RYR2 | c.12630C>A p.D4210E | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.109); catalogued as COSV63685740; called by muse, mutect2, varscan2
- S100A7A | c.263A>G p.K88R | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV100241679; called by muse, mutect2, varscan2
- SCN11A | c.4516C>G p.L1506V | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100182596; called by muse, mutect2, varscan2
- SCN11A | c.1689G>T p.W563C | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100182597; called by muse, mutect2, varscan2
- SCN5A | c.3584G>T p.R1195L (on ENST00000333535 / NM_198056.3; = p.R1194L on NM_000335.5) | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM098020, COSV100350649, COSV61124717; called by muse, mutect2, varscan2
- SDK2 | c.2515G>T p.E839* | Nonsense Mutation (SNP) | VAF 23/47 reads (49%) | catalogued as COSV101168661; called by muse, mutect2, varscan2
- SEC16B | c.2776G>T p.A926S | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as COSV100381421, COSV100381954; called by muse, mutect2, varscan2
- SEMA5A | c.1778C>T p.S593F | Missense Mutation (SNP) | VAF 57/118 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101228735, COSV66789964; called by muse, mutect2, varscan2
- SEMA5B | c.2133-1G>T p.X711_splice | Splice Site (SNP) | VAF 5/61 reads (8%) | catalogued as rs1355669562, COSV52101119; called by muse, mutect2
- SEMA6D | c.1057G>C p.V353L | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.574); catalogued as COSV100316971, COSV100317649; called by muse, mutect2, varscan2
- SERPINF1 | c.138C>G p.F46L | Missense Mutation (SNP) | VAF 24/150 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.025); catalogued as COSV99628985; called by muse, varscan2
- SERPINI1 | c.986A>G p.K329R | Missense Mutation (SNP) | VAF 49/127 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV55515756; called by mutect2, varscan2
- SF1 | c.207C>A p.D69E | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.299); catalogued as COSV99918815; called by muse, mutect2, varscan2
- SHPRH | c.1772C>T p.P591L | Missense Mutation (SNP) | VAF 68/329 reads (21%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as COSV99262713; called by muse, mutect2, varscan2
- SIGLEC6 | c.369G>T p.L123F | Missense Mutation (SNP) | VAF 82/189 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV100585694; called by muse, mutect2, varscan2
- SKAP1 | c.55G>T p.E19* | Nonsense Mutation (SNP) | VAF 83/245 reads (34%) | catalogued as COSV100412343, COSV61153949; called by muse, mutect2, varscan2
- SLC12A1 | c.312C>A p.N104K | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV100372589; called by muse, mutect2, varscan2
- SLC13A4 | c.625A>T p.N209Y | Missense Mutation (SNP) | VAF 45/210 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.078); catalogued as COSV100818967; called by muse, mutect2, varscan2
- SLC17A6 | c.233G>C p.G78A | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.403); catalogued as COSV99582436; called by muse, mutect2, varscan2
- SLC17A8 | c.1216G>A p.V406M | Missense Mutation (SNP) | VAF 41/344 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV100035880; called by muse, mutect2, varscan2
- SLC17A8 | c.1521G>T p.Q507H | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1323945703, COSV100035883; called by muse, mutect2, varscan2
- SLC24A2 | c.409C>A p.L137M | Missense Mutation (SNP) | VAF 50/167 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99647465; called by muse, mutect2, varscan2
- SLC36A4 | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.025); catalogued as rs375634223, COSV58395851; called by muse, mutect2, varscan2
- SLC38A6 | c.401G>T p.G134V | Missense Mutation (SNP) | VAF 80/258 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99960108; called by muse, mutect2, varscan2
- SLC8A1 | c.1183G>T p.E395* | Nonsense Mutation (SNP) | VAF 89/159 reads (56%) | catalogued as COSV100247466, COSV60479878; called by muse, mutect2, varscan2
- SLIT1 | c.2258G>T p.R753L | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV56595990, COSV99822568; called by muse, mutect2, varscan2
- SLIT3 | c.4409C>G p.A1470G | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.071); catalogued as COSV100270014; called by muse, mutect2, varscan2
- SLITRK4 | c.339C>A p.H113Q | Missense Mutation (SNP) | VAF 41/160 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100567526; called by muse, mutect2, varscan2
- SMC6 | c.365C>T p.T122I | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.604); catalogued as COSV100705360; called by muse, mutect2, varscan2
- SOGA3 | c.1912C>T p.Q638* | Nonsense Mutation (SNP) | VAF 11/112 reads (10%) | catalogued as COSV100847074; called by muse, mutect2
- SORCS3 | c.716C>T p.T239I | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as COSV100865664; called by muse, mutect2
- SP4 | c.583C>G p.Q195E | Missense Mutation (SNP) | VAF 38/218 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as COSV99755075; called by muse, varscan2
- SPAM1 | c.1204C>A p.P402T | Missense Mutation (SNP) | VAF 85/193 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV99773495; called by muse, mutect2, varscan2
- SPEM1 | c.383G>T p.W128L | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (0.07); PolyPhen benign (0.101); catalogued as COSV100081288; called by muse, mutect2, varscan2
- SPEN | c.1694C>T p.A565V | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1157570058, COSV101005626; called by muse, mutect2, varscan2
- SPEN | c.2342G>A p.R781H | Missense Mutation (SNP) | VAF 31/163 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as rs778639822, COSV101005627; called by muse, mutect2, varscan2
- SPICE1 | c.1507del p.E503Kfs*17 | Frame Shift Del (DEL) | VAF 30/191 reads (16%) | catalogued as COSV55625270; called by mutect2, pindel, varscan2
- SPIDR | c.1586A>G p.E529G | Missense Mutation (SNP) | VAF 69/295 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99856090; called by muse, mutect2, varscan2
- SPPL2C | c.210C>A p.C70* | Nonsense Mutation (SNP) | VAF 21/51 reads (41%) | catalogued as COSV100234165; called by muse, mutect2, varscan2
- SPTA1 | c.5195A>G p.K1732R | Missense Mutation (SNP) | VAF 31/234 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV100934623, COSV100935599; called by muse, mutect2, varscan2
- SSBP1 | c.229G>T p.D77Y | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99519850; called by muse, mutect2, varscan2
- SSTR4 | c.1070C>A p.A357E | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT tolerated (0.52); PolyPhen benign (0.011); catalogued as COSV99658809; called by muse, mutect2, varscan2
- ST18 | c.2782C>A p.H928N | Missense Mutation (SNP) | VAF 21/171 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.046); catalogued as COSV99391075; called by muse, mutect2, varscan2
- ST18 | c.688C>A p.L230I | Missense Mutation (SNP) | VAF 28/219 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV99391076; called by muse, mutect2, varscan2
- ST6GALNAC2 | c.341G>T p.W114L | Missense Mutation (SNP) | VAF 16/44 reads (36%) | PolyPhen probably damaging (0.965); catalogued as COSV56572048; called by muse, mutect2, varscan2
- STRC | c.5141T>C p.V1714A | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs568263767, COSV100294700; called by mutect2, varscan2
- STRN3 | c.2090T>C p.I697T (on ENST00000357479 / NM_001083893.2; = p.I613T on NM_014574.4) | Missense Mutation (SNP) | VAF 28/406 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.165); catalogued as COSV100671035; called by muse, mutect2
- STXBP4 | c.288-1G>A p.X96_splice | Splice Site (SNP) | VAF 18/53 reads (34%) | catalogued as COSV100178421; called by muse, mutect2, varscan2
- SUGCT | c.135A>T p.K45N | Missense Mutation (SNP) | VAF 42/624 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); catalogued as COSV100004693; called by muse, mutect2
- SULT2B1 | c.697G>T p.G233C (on ENST00000201586 / NM_177973.2; = p.G218C on NM_004605.2) | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); catalogued as COSV99572455; called by muse, mutect2, varscan2
- SUN5 | c.486G>T p.M162I | Missense Mutation (SNP) | VAF 117/402 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100644913, COSV62182527; called by muse, mutect2, varscan2
- SVEP1 | c.4505G>A p.C1502Y | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100239120; called by muse, mutect2, varscan2
- SYNE2 | c.4934T>C p.L1645P | Missense Mutation (SNP) | VAF 101/252 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV100648512; called by muse, mutect2, varscan2
- TAB3 | c.1238G>T p.G413V | Missense Mutation (SNP) | VAF 50/148 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as COSV99916845; called by muse, mutect2, varscan2
- TAF1C | c.2153G>T p.S718I | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as rs571590962, COSV100499794; called by muse, mutect2, varscan2
- TANC1 | c.4882G>A p.E1628K | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.129); catalogued as COSV99715245; called by muse, mutect2
- TARS1 | c.2041A>G p.K681E | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.049); catalogued as COSV54307803; called by muse, mutect2, varscan2
- TARS3 | c.2020G>T p.G674* | Nonsense Mutation (SNP) | VAF 18/113 reads (16%) | catalogued as COSV100255053; called by muse, mutect2, varscan2
- TAS1R2 | c.689G>C p.R230P | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.153); catalogued as COSV100946387; called by muse, mutect2, varscan2
- TBX5 | c.350C>A p.A117E | Missense Mutation (SNP) | VAF 124/290 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.947); catalogued as COSV100092194; called by muse, varscan2
- TCF23 | c.314C>A p.A105D | Missense Mutation (SNP) | VAF 64/116 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV56078504, COSV99940419; called by muse, mutect2, varscan2
- TET1 | c.4771G>T p.G1591C | Missense Mutation (SNP) | VAF 44/234 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1424143762, COSV101018918; called by muse, mutect2, varscan2
- TET1 | c.4772G>T p.G1591V | Missense Mutation (SNP) | VAF 41/227 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV101018919; called by muse, mutect2, varscan2
- TEX13A | c.1099C>G p.H367D | Missense Mutation (SNP) | VAF 51/169 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.084); catalogued as COSV100782073; called by muse, mutect2, varscan2
- TEX2 | c.1862A>T p.K621I | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.344); catalogued as COSV99367521; called by muse, mutect2, varscan2
- TEX47 | c.736G>C p.V246L | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV99787396; called by muse, mutect2, varscan2
- TG | c.6263-2A>G p.X2088_splice | Splice Site (SNP) | VAF 50/1269 reads (4%) | catalogued as COSV99603290; called by muse, mutect2
- TJP3 | c.2486C>T p.P829L | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV99516502; called by muse, mutect2
- TKTL2 | c.1781C>T p.S594L | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.022); catalogued as COSV99761749; called by muse, mutect2, varscan2
- TLR4 | c.1955A>G p.Y652C (on ENST00000355622 / NM_138554.5; = p.Y612C on NM_003266.4) | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201792813, COSV62923346; called by muse, mutect2, varscan2
- TM7SF3 | c.1064G>T p.G355V | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100545020; called by muse, mutect2
- TMC1 | c.1441C>A p.L481I | Missense Mutation (SNP) | VAF 77/311 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV52772546, COSV52788600; called by muse, mutect2, varscan2
- TMEM132B | c.2510C>A p.P837H | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.298); catalogued as COSV100170963; called by muse, mutect2
- TMEM132E | c.2867G>T p.W956L (on ENST00000321639; = p.W1046L on NM_001304438.2) | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100396811; called by muse, varscan2
- TMEM222 | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.14); catalogued as rs757014818, COSV65026941; called by muse, mutect2, varscan2
- TMEM74 | c.209C>A p.S70Y | Missense Mutation (SNP) | VAF 203/371 reads (55%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as rs145073892, COSV99865938; called by muse, mutect2, varscan2
- TMLHE | c.12C>A p.H4Q | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.01); catalogued as COSV100545110; called by muse, mutect2, varscan2
- TMPRSS11F | c.638C>G p.A213G | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as rs757125206, COSV100678824; called by muse, mutect2, varscan2
- TMTC2 | c.1147C>A p.Q383K | Missense Mutation (SNP) | VAF 116/265 reads (44%) | SIFT tolerated (0.9); PolyPhen benign (0.01); catalogued as COSV100338880; called by muse, mutect2, varscan2
- TNFRSF11B | c.366G>C p.R122S | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT tolerated (0.7); PolyPhen benign (0.08); catalogued as COSV99816337, COSV99816980; called by muse, mutect2, varscan2
- TNNT3 | c.234C>A p.D78E (on ENST00000397301 / NM_001367846.1; = p.D67E on NM_006757.4) | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99548771; called by muse, mutect2, varscan2
- TNR | c.292C>A p.L98M | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV54896013, COSV99691669; called by muse, mutect2, varscan2
- TNS4 | c.1207G>T p.A403S | Missense Mutation (SNP) | VAF 48/384 reads (13%) | SIFT tolerated (0.62); PolyPhen benign (0.006); catalogued as rs912729493, COSV99564167; called by muse, mutect2, varscan2
- TPD52 | c.555G>A p.K185= (on ENST00000379097 / NM_001025252.3; = p.K145= on NM_005079.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 32/220 reads (15%) | catalogued as COSV100990900; called by muse, mutect2, varscan2
- TPP2 | c.2278C>G p.P760A | Missense Mutation (SNP) | VAF 23/210 reads (11%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV101060450; called by muse, mutect2, varscan2
- TPTE2 | c.364G>A p.D122N (on ENST00000400230 / NM_199254.2; = p.D85N on NM_130785.3) | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1380842711, COSV99691018; called by muse, mutect2, varscan2
- TRAV18 | c.102G>C p.E34D | Missense Mutation (SNP) | VAF 15/158 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.422); catalogued as rs779604623; called by muse, mutect2, varscan2
- TREX2 | c.245C>T p.S82F (on ENST00000334497; = p.S39F on NM_080701.3) | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100444324; called by muse, mutect2, varscan2
- TRIM29 | c.748C>T p.Q250* | Nonsense Mutation (SNP) | VAF 43/137 reads (31%) | catalogued as COSV100532030; called by muse, mutect2, varscan2
- TRIM42 | c.1319T>C p.V440A | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.967); catalogued as COSV99648850; called by muse, mutect2, varscan2
- TRIM56 | c.1949G>T p.G650V | Missense Mutation (SNP) | VAF 106/287 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV100047764; called by muse, mutect2, varscan2
- TRIM6 | c.181A>G p.T61A | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0.083); catalogued as COSV99546854; called by muse, mutect2, varscan2
- TROAP | c.1729G>C p.V577L | Missense Mutation (SNP) | VAF 66/148 reads (45%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.007); catalogued as COSV57744689, COSV99227029; called by muse, varscan2
- TRRAP | c.2925G>A p.M975I | Missense Mutation (SNP) | VAF 20/290 reads (7%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV100723008; called by muse, mutect2
- TRRAP | c.2926A>T p.S976C | Missense Mutation (SNP) | VAF 20/290 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV100723009; called by muse, mutect2
- TTC17 | c.2272A>C p.N758H | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.768); catalogued as COSV99234474, COSV99236063; called by muse, mutect2, varscan2
- TTC27 | c.2132T>A p.I711N | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as COSV100513618; called by muse, mutect2, varscan2
- TUBA4A | c.494C>T p.S165F | Missense Mutation (SNP) | VAF 90/131 reads (69%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.912); catalogued as COSV99944994; called by muse, mutect2, varscan2
- TUT4 | c.1898G>T p.W633L | Missense Mutation (SNP) | VAF 21/181 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.563); catalogued as COSV99932851; called by muse, mutect2, varscan2
- TXNDC2 | c.177G>T p.Q59H | Missense Mutation (SNP) | VAF 49/85 reads (58%) | SIFT tolerated (0.67); PolyPhen benign (0.014); catalogued as COSV100046593; called by muse, mutect2, varscan2
- UGT2B15 | c.235A>G p.T79A | Missense Mutation (SNP) | VAF 62/226 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.02); catalogued as rs779527968, COSV100592461; called by muse, mutect2, varscan2
- UGT3A1 | c.1403C>A p.A468E | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs141907677, COSV57095854; called by muse, mutect2, varscan2
- UMOD | c.718G>T p.E240* | Nonsense Mutation (SNP) | VAF 15/22 reads (68%) | catalogued as rs1321919119, COSV100208702; called by muse, mutect2, varscan2
- UNC45A | c.1654G>T p.A552S | Missense Mutation (SNP) | VAF 51/171 reads (30%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.991); catalogued as COSV101266053; called by muse, mutect2, varscan2
- UNC79 | c.6904C>A p.L2302M (on ENST00000393151 / NM_001346218.2; = p.L2125M on NM_020818.5) | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.041); catalogued as COSV99829886; called by muse, mutect2
- UROC1 | c.1817G>T p.G606V | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99332421; called by muse, mutect2
- USH2A | c.5285C>A p.P1762H | Missense Mutation (SNP) | VAF 20/242 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as COSV56439680; called by muse, mutect2
- USH2A | c.2167G>A p.G723R | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100230446, COSV100242898; called by muse, mutect2
- USHBP1 | c.1570C>A p.H524N | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.374); catalogued as COSV99394548; called by muse, mutect2, varscan2
- USO1 | c.1330C>A p.L444I | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.916); catalogued as COSV99363223; called by muse, mutect2, varscan2
- USP38 | c.3043G>C p.D1015H | Missense Mutation (SNP) | VAF 110/285 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100189496; called by muse, mutect2, varscan2
- UTS2 | c.254G>A p.R85K | Missense Mutation (SNP) | VAF 38/75 reads (51%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as rs1232827044, COSV99276960; called by muse, mutect2, varscan2
- VIRMA | c.1130G>T p.G377V | Missense Mutation (SNP) | VAF 85/597 reads (14%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.999); catalogued as COSV99889505; called by muse, mutect2, varscan2
- VSTM2A | c.229G>T p.E77* | Nonsense Mutation (SNP) | VAF 22/35 reads (63%) | catalogued as COSV100173375; called by muse, mutect2, varscan2
- VWA2 | c.1235G>C p.G412A | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100073986; called by muse, mutect2, varscan2
- WASF1 | c.644A>T p.E215V | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.189); catalogued as COSV99661516; called by muse, mutect2, varscan2
- WDFY3 | c.4437G>T p.L1479F | Missense Mutation (SNP) | VAF 56/192 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99885743; called by muse, mutect2, varscan2
- WDR17 | c.556A>T p.K186* | Nonsense Mutation (SNP) | VAF 35/243 reads (14%) | catalogued as COSV99708302; called by muse, mutect2, varscan2
- WDR7 | c.613T>C p.F205L | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as COSV99590480; called by muse, mutect2, varscan2
- WIPF1 | c.347A>G p.N116S | Missense Mutation (SNP) | VAF 209/421 reads (50%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs749246531, COSV99769487; called by muse, mutect2, varscan2
- WWC3 | c.2167C>G p.H723D | Missense Mutation (SNP) | VAF 22/191 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as COSV101081851; called by muse, mutect2, varscan2
- WWP1 | c.1235C>T p.P412L | Missense Mutation (SNP) | VAF 56/278 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99617242; called by muse, mutect2
- WWP1 | c.1237A>T p.T413S | Missense Mutation (SNP) | VAF 58/284 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.574); catalogued as COSV99617243; called by muse, mutect2
- XKR6 | c.908T>C p.L303P | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100441133; called by muse, mutect2, varscan2
- ZAN | c.95C>A p.S32Y | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100770375; called by muse, mutect2, varscan2
- ZBED8 | c.430G>A p.D144N | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.733); catalogued as COSV68824961; called by muse, mutect2, varscan2
- ZBP1 | c.1258C>T p.H420Y | Missense Mutation (SNP) | VAF 47/150 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV100473980; called by muse, mutect2, varscan2
- ZBTB37 | c.497G>A p.R166Q | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated (0.64); PolyPhen benign (0.034); catalogued as rs140815439; called by muse, mutect2, varscan2
- ZC3H12B | c.1886C>A p.P629H | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.121); catalogued as COSV100162059; called by muse, mutect2, varscan2
- ZC3H7A | c.1820+1G>T p.X607_splice | Splice Site (SNP) | VAF 108/190 reads (57%) | catalogued as COSV100865609; called by muse, mutect2, varscan2
- ZDHHC15 | c.283G>T p.E95* | Nonsense Mutation (SNP) | VAF 33/90 reads (37%) | catalogued as COSV100973894; called by muse, mutect2, varscan2
- ZEB2 | c.587A>T p.E196V | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100356935; called by muse, mutect2, varscan2
- ZFP42 | c.875T>A p.L292Q | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.261); catalogued as COSV100479164; called by muse, mutect2, varscan2
- ZIK1 | c.733G>T p.G245W | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100277667, COSV56738657; called by muse, mutect2, varscan2
- ZKSCAN8 | c.1441C>T p.Q481* | Nonsense Mutation (SNP) | VAF 8/116 reads (7%) | catalogued as COSV100363041; called by muse, mutect2
- ZMIZ2 | c.2363C>T p.P788L | Missense Mutation (SNP) | VAF 85/198 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as COSV99536663, COSV99537220; called by muse, mutect2, varscan2
- ZNF106 | c.2623A>T p.S875C | Missense Mutation (SNP) | VAF 42/131 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.72); catalogued as COSV99783199; called by muse, mutect2, varscan2
- ZNF112 | c.2252G>T p.C751F (on ENST00000337401 / NM_001083335.2; = p.C745F on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 145/299 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100496295; called by muse, mutect2, varscan2
- ZNF223 | c.754A>G p.K252E | Missense Mutation (SNP) | VAF 161/306 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.935); catalogued as COSV101462658; called by muse, mutect2, varscan2
- ZNF257 | c.1484C>A p.A495D | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.267); catalogued as COSV101448170; called by muse, mutect2, varscan2
- ZNF354A | c.1334A>T p.K445I | Missense Mutation (SNP) | VAF 77/192 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100234653; called by muse, mutect2, varscan2
- ZNF365 | c.277A>C p.K93Q | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.238); catalogued as COSV101237998; called by muse, mutect2, varscan2
- ZNF423 | c.710G>A p.R237H (on ENST00000563137 / NM_001379286.1; = p.R229H on NM_015069.4) | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1269407799, COSV52175713, COSV52178946; called by muse, mutect2, varscan2
- ZNF429 | c.1576C>A p.Q526K | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs878915708, COSV100642052; called by muse, mutect2, varscan2
- ZNF48 | c.1588C>T p.P530S | Missense Mutation (SNP) | VAF 81/181 reads (45%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV100198227; called by muse, mutect2, varscan2
- ZNF534 | c.327G>C p.L109F (on ENST00000332323 / NM_001143939.3; = p.L96F on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.855); catalogued as COSV56514068, COSV99989793, COSV99990209; called by muse, mutect2, varscan2
- ZNF563 | c.1129A>C p.S377R | Missense Mutation (SNP) | VAF 154/309 reads (50%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as COSV99536802; called by muse, mutect2, varscan2
- ZNF597 | c.726T>A p.C242* | Nonsense Mutation (SNP) | VAF 246/385 reads (64%) | catalogued as COSV100072172; called by muse, mutect2, varscan2
- ZNF619 | c.1531G>T p.V511L | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100123379; called by muse, mutect2
- ZNF644 | c.1337G>A p.R446K | Missense Mutation (SNP) | VAF 93/211 reads (44%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.97); catalogued as COSV100494739; called by muse, mutect2, varscan2
- ZNF676 | c.1681G>A p.G561R (on ENST00000650058; = p.G529R on NM_001001411.3) | Missense Mutation (SNP) | VAF 76/158 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.622); catalogued as rs192028972, COSV101236351; called by muse, mutect2, varscan2
- ZNF804A | c.2010T>A p.N670K | Missense Mutation (SNP) | VAF 32/184 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV100170263; called by muse, mutect2, varscan2
- ZNF813 | c.788G>T p.R263I | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV101124751; called by muse, mutect2, varscan2
- ZNF823 | c.397G>A p.E133K (on ENST00000341191 / NM_001297610.2; = p.E89K on NM_017507.2) | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.993); catalogued as COSV100362653; called by muse, varscan2
- ZNF98 | c.70C>G p.L24V | Missense Mutation (SNP) | VAF 65/144 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.19); catalogued as COSV100757630, COSV63339170; called by muse, mutect2, varscan2
- ZUP1 | c.1206G>T p.K402N | Missense Mutation (SNP) | VAF 84/129 reads (65%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV100885152; called by muse, mutect2, varscan2
- ACACA | c.1799G>T p.W600L | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACSM2B | c.1129A>T p.K377* | Nonsense Mutation (SNP) | VAF 20/419 reads (5%) | called by muse, mutect2
- ACTB | c.424dup p.L142Pfs*16 | Frame Shift Ins (INS) | VAF 28/264 reads (11%) | called by pindel, varscan2
- ACTRT2 | c.970_971insG p.S324Cfs*30 | Frame Shift Ins (INS) | VAF 30/87 reads (34%) | called by mutect2, pindel*, varscan2
- ANXA8 | c.252G>T p.E84D | Missense Mutation (SNP) | VAF 68/417 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ARHGEF26 | c.615del p.Q207Rfs*29 | Frame Shift Del (DEL) | VAF 27/99 reads (27%) | called by mutect2, pindel, varscan2
- ARID4A | c.3770G>T p.R1257M | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- CCDC178 | c.915dup p.E306* | Frame Shift Ins (INS) | VAF 16/62 reads (26%) | called by mutect2, pindel, varscan2
- CEP83 | c.403del p.R135Gfs*3 | Frame Shift Del (DEL) | VAF 42/116 reads (36%) | called by mutect2, pindel, varscan2
- CSMD2 | c.8623dup p.C2875Lfs*13 | Frame Shift Ins (INS) | VAF 13/50 reads (26%) | called by mutect2, pindel, varscan2
- CWC25 | c.991G>T p.G331* | Nonsense Mutation (SNP) | VAF 5/38 reads (13%) | called by muse, mutect2
- DCHS1 | c.3791del p.F1264Sfs*16 | Frame Shift Del (DEL) | VAF 12/48 reads (25%) | called by pindel, varscan2
- GABRA3 | c.1102del p.A368Lfs*13 | Frame Shift Del (DEL) | VAF 31/122 reads (25%) | called by mutect2, pindel, varscan2
- IGDCC3 | c.766G>A p.V256M | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.438); called by muse, mutect2
- IGKV4-1 | c.58G>T p.G20W | Missense Mutation (SNP) | VAF 50/88 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, varscan2
- KCNC1 | c.803_804del p.P268Qfs*14 | Frame Shift Del (DEL) | VAF 29/230 reads (13%) | called by mutect2, pindel, varscan2
- OR2T2 | c.8T>A p.M3K | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.441); called by mutect2, varscan2
- OR3A1 | c.483_484del p.T163Cfs*20 | Frame Shift Del (DEL) | VAF 42/135 reads (31%) | called by mutect2, varscan2
- PAQR9 | c.841T>A p.Y281N | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.781); called by muse, mutect2
- PKD2L1 | c.650G>T p.R217L | Missense Mutation (SNP) | VAF 28/151 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- PTBP2 | c.1448dup p.A484Rfs*2 (on ENST00000426398 / NM_001300986.2; = p.A476Rfs*2 on NM_021190.4) | Frame Shift Ins (INS) | VAF 80/244 reads (33%) | called by pindel, varscan2
- RBFOX2 | c.979C>T p.P327S (on ENST00000438146 / NM_001349995.2; = p.P253S on NM_014309.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.84); called by muse, mutect2
- RIPK2 | c.22A>G p.S8G | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.073); called by muse, mutect2
- SEMG2 | c.305del p.G102Efs*24 | Frame Shift Del (DEL) | VAF 38/163 reads (23%) | called by mutect2, pindel, varscan2
- SPATA31A1 | c.3455C>A p.P1152Q | Missense Mutation (SNP) | VAF 26/418 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.64); called by muse, mutect2
- TBC1D8 | c.672del p.Q225Rfs*11 | Frame Shift Del (DEL) | VAF 38/86 reads (44%) | called by mutect2, pindel, varscan2
- TEX13A | c.638C>A p.P213H | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.953); called by muse, mutect2
- TRBV28 | c.283C>A p.L95M | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRGV2 | c.45C>A p.A15= | Splice Region (SNP) | VAF 56/178 reads (31%) | called by muse, varscan2
- ZNF84 | c.1307G>T p.C436F | Missense Mutation (SNP) | VAF 30/256 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABCB1 | c.3246C>A p.L1082= | Silent (SNP) | VAF 21/96 reads (22%) | catalogued as COSV55957838, COSV99714465; called by muse, mutect2, varscan2
- ACSS3 | c.372T>C p.G124= | Silent (SNP) | VAF 29/165 reads (18%) | catalogued as COSV99699475; called by muse, mutect2, varscan2
- ADAMTS9 | c.2760G>T p.R920= | Silent (SNP) | VAF 40/77 reads (52%) | catalogued as COSV99900247; called by muse, mutect2, varscan2
- APOA4 | c.549C>T p.A183= | Silent (SNP) | VAF 36/426 reads (8%) | catalogued as rs1266040326, COSV100759395; called by muse, mutect2
- ARHGAP31 | c.54G>C p.A18= | Silent (SNP) | VAF 7/108 reads (6%) | catalogued as COSV99957751; called by muse, mutect2
- ARHGAP39 | c.2301C>T p.A767= | Silent (SNP) | VAF 18/79 reads (23%) | catalogued as COSV99432285; called by muse, mutect2, varscan2
- ARHGEF17 | c.5094G>A p.G1698= | Silent (SNP) | VAF 20/33 reads (61%) | catalogued as COSV99736816; called by muse, mutect2, varscan2
- ARID1B | c.1842G>C p.A614= | Silent (SNP) | VAF 22/39 reads (56%) | catalogued as rs146312104, COSV51683891; called by muse, mutect2, varscan2
- ART1 | c.381G>T p.L127= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV99167262; called by muse, mutect2, varscan2
- ASMT | c.411T>A p.V137= | Silent (SNP) | VAF 94/466 reads (20%) | catalogued as COSV101172545; called by muse, mutect2, varscan2
- ASTN2 | c.1953A>T p.P651= (on ENST00000313400 / NM_001365069.1; = p.P600= on NM_014010.5) | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as COSV100530382; called by muse, mutect2, varscan2
- BCOR | c.5211G>T p.L1737= (on ENST00000378444 / NM_001123385.2; = p.L1703= on NM_017745.6) | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV100654176; called by muse, mutect2, varscan2
- BOK | c.447C>T p.L149= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs140733714; called by muse, mutect2
- C10orf90 | c.2094G>A p.A698= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as rs933940313, COSV52951465, COSV99504432; called by muse, mutect2, varscan2
- C1orf158 | c.243C>T p.H81= | Silent (SNP) | VAF 31/317 reads (10%) | catalogued as rs200483207, COSV55346495; called by muse, mutect2
- C9orf131 | c.2988C>A p.G996= | Silent (SNP) | VAF 36/174 reads (21%) | catalogued as COSV100398323; called by muse, varscan2
- CCDC57 | c.1257G>T p.L419= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as COSV100492678; called by muse, mutect2, varscan2
- CCP110 | c.2271C>T p.N757= | Silent (SNP) | VAF 20/184 reads (11%) | catalogued as rs375415222; called by muse, mutect2, varscan2
- CD5 | c.1041G>C p.L347= | Silent (SNP) | VAF 13/78 reads (17%) | catalogued as COSV100759912; called by muse, mutect2, varscan2
- CD86 | c.150G>C p.L50= (on ENST00000330540 / NM_175862.5; = p.L44= on NM_006889.4) | Silent (SNP) | VAF 32/188 reads (17%) | catalogued as COSV100054192; called by muse, mutect2, varscan2
- CDH6 | c.924A>G p.T308= | Silent (SNP) | VAF 21/151 reads (14%) | catalogued as COSV99420889; called by muse, mutect2, varscan2
- CHL1 | c.3159C>A p.G1053= (on ENST00000397491 / NM_001253387.1; = p.G1069= on NM_006614.4) | Silent (SNP) | VAF 56/119 reads (47%) | catalogued as COSV99852373; called by muse, mutect2, varscan2
- CKMT1A | c.978A>T p.A326= | Silent (SNP) | VAF 40/136 reads (29%) | catalogued as COSV100787740; called by muse, mutect2, varscan2
- CLDN8 | c.312C>T p.C104= | Silent (SNP) | VAF 39/88 reads (44%) | catalogued as COSV99730011; called by muse, mutect2, varscan2
- CLDN8 | c.165G>C p.V55= | Silent (SNP) | VAF 31/253 reads (12%) | catalogued as COSV99730013; called by muse, mutect2, varscan2
- CNGB3 | c.630A>T p.I210= | Silent (SNP) | VAF 124/618 reads (20%) | catalogued as COSV100183093, COSV60692952; called by muse, varscan2
- CNNM3 | c.1932G>A p.L644= | Silent (SNP) | VAF 87/138 reads (63%) | catalogued as COSV100562796; called by muse, mutect2, varscan2
- CNTN6 | c.2136A>C p.G712= | Silent (SNP) | VAF 96/242 reads (40%) | catalogued as rs1229103195, COSV100611865; called by muse, mutect2, varscan2
- COL4A5 | c.4515G>T p.T1505= | Silent (SNP) | VAF 28/96 reads (29%) | catalogued as rs370327284, COSV100089613, COSV60360182; called by muse, mutect2, varscan2
- CRLF2 | c.468C>T p.F156= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as rs755785714, COSV67493750; called by muse, mutect2, varscan2
- CTNNA2 | c.1185C>A p.T395= | Silent (SNP) | VAF 108/191 reads (57%) | catalogued as COSV100562065; called by muse, mutect2, varscan2
- CTNS | c.624C>T p.F208= | Silent (SNP) | VAF 16/109 reads (15%) | catalogued as rs771057130, COSV99251567; called by muse, mutect2, varscan2
- DKK1 | c.177A>T p.A59= | Silent (SNP) | VAF 23/90 reads (26%) | catalogued as COSV100906590; called by muse, mutect2, varscan2
- DNAH11 | c.1701T>A p.A567= | Silent (SNP) | VAF 63/258 reads (24%) | catalogued as COSV100180950; called by muse, mutect2, varscan2
- DRD5 | c.1062C>T p.L354= | Silent (SNP) | VAF 58/118 reads (49%) | catalogued as COSV100432041; called by muse, mutect2, varscan2
- DSG4 | c.2352G>A p.S784= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as rs1441356137, COSV57388978; called by muse, mutect2, varscan2
169 further variants in this file (0 protein-altering or splice-affecting, 147 silent, 22 other) are not listed here.
